Somatic mutation profile of tumor specimen MMRF_2535_1_BM_CD138pos (aliquot MMRF_2535_1_BM_CD138pos_T1_KHS5U_L13314) from MMRF case MMRF_2535, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 46.6 years (17,034 days).
Specimen MMRF_2535_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 55566eed-ecc0-46dd-8073-603c9bcddaef.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2535_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2535_1_PB_WBC_C3_KHS5U_L13315; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/822bcccb-af63-47e0-a0d6-b98e1b536c9d

The open-access MAF lists 963 somatic variants for this specimen: 340 protein-altering or splice-affecting, 153 silent, 470 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 295, 3'UTR 253, Silent 153, Intron 102, 5'UTR 56, 5'Flank 27, Nonsense Mutation 25, RNA 20, 3'Flank 12, Splice Site 9, Splice Region 7, Translation Start Site 2.

Variants (750 of 963; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CPLANE1 | chr5:37168945 del G | 3'Flank (DEL) | VAF 55/374 reads (15%) | catalogued as rs1085307795, COSV57052897; ClinVar: pathogenic; called by mutect2, varscan2
- KRAS | c.*22C>G | 3'UTR (SNP) | VAF 8/82 reads (10%) | catalogued as rs104894362, CM070970, COSV55666258, COSV56095155; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.181C>G p.Q61E | Missense Mutation (SNP) | VAF 15/68 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.509); catalogued as rs121913238, COSV55502066, COSV55502677; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.596G>T p.G199V | Missense Mutation (SNP) | VAF 19/164 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1555525857, COSV52661319, COSV52679535, COSV53326529; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.130C>T p.R44C | Missense Mutation (SNP) | VAF 14/104 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs546968040; called by mutect2, varscan2
- ADAM11 | c.1511G>A p.R504Q | Missense Mutation (SNP) | VAF 22/130 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs775938319, COSV52344380; called by muse, mutect2, varscan2
- ADNP2 | c.1271C>T p.S424F | Missense Mutation (SNP) | VAF 23/145 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs1171693807; called by muse, mutect2, varscan2
- AHCYL1 | c.1420G>A p.E474K | Missense Mutation (SNP) | VAF 28/212 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.111); catalogued as rs750092870, COSV63208745; called by muse, mutect2, varscan2
- AKAP9 | c.7585G>A p.E2529K (on ENST00000359028; = p.E2505K on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.513); catalogued as COSV62348304; called by muse, mutect2, varscan2
- APC | c.730-1G>A p.X244_splice | Splice Site (SNP) | VAF 16/153 reads (10%) | catalogued as CS941417, COSV57335072; called by muse, varscan2
- ARG2 | c.41G>A p.R14Q | Missense Mutation (SNP) | VAF 16/131 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1457192899; called by muse, mutect2, varscan2
- ARHGAP24 | c.1633G>A p.D545N (on ENST00000395184 / NM_001025616.3; = p.D452N on NM_031305.3) | Missense Mutation (SNP) | VAF 46/258 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.149); catalogued as rs1560774439; called by muse, mutect2, varscan2
- ATAD3C | c.955C>A p.L319I | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.127); catalogued as COSV101112718; called by muse, mutect2, varscan2
- ATP10A | c.2060C>G p.S687* | Nonsense Mutation (SNP) | VAF 19/97 reads (20%) | catalogued as COSV63521582; called by muse, mutect2
- BRINP3 | c.2041C>T p.R681W | Missense Mutation (SNP) | VAF 23/153 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as rs199983605, COSV66532306, COSV66534597; called by muse, mutect2, varscan2
- C17orf107 | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 22/172 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.741); catalogued as rs771447345; called by muse, mutect2, varscan2
- CACNA1B | c.3196C>T p.R1066C | Missense Mutation (SNP) | VAF 32/201 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs769500676; called by muse, mutect2, varscan2
- CARMIL1 | c.4099G>A p.E1367K | Missense Mutation (SNP) | VAF 34/243 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.185); catalogued as rs774052696, COSV61519781; called by muse, varscan2
- CCDC87 | c.1180C>T p.R394C | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs374929199; called by muse, mutect2, varscan2
- CCNI2 | c.615A>C p.K205N | Missense Mutation (SNP) | VAF 58/131 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs548714263; called by muse, mutect2, varscan2
- CDC14A | c.118G>A p.D40N | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs1409508177; called by muse, mutect2
- CEACAM5 | c.1973C>T p.S658F | Missense Mutation (SNP) | VAF 40/227 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.166); catalogued as COSV55755732; called by muse, varscan2
- CEP152 | c.3589C>T p.Q1197* | Nonsense Mutation (SNP) | VAF 14/98 reads (14%) | catalogued as rs1185530126; called by muse, mutect2, varscan2
- CHD2 | c.2782C>T p.R928W | Missense Mutation (SNP) | VAF 43/94 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs765497208, COSV67708564; called by muse, mutect2, varscan2
- CHRM3 | c.1334C>T p.S445F | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as rs143159997; called by muse, mutect2, varscan2
- CNEP1R1 | c.235G>C p.G79R (on ENST00000427478 / NM_001281789.1; = p.G96R on NM_153261.5) | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.066); catalogued as COSV101208067; called by muse, varscan2
- COL5A2 | c.1390C>T p.R464* | Nonsense Mutation (SNP) | VAF 6/85 reads (7%) | catalogued as COSV66412259; called by muse, mutect2
- CPNE4 | c.1268C>G p.S423* | Nonsense Mutation (SNP) | VAF 7/96 reads (7%) | catalogued as COSV101456564; called by muse, mutect2
- CTNNA2 | c.886G>A p.E296K | Missense Mutation (SNP) | VAF 48/117 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.251); catalogued as COSV100786959; called by muse, mutect2, varscan2
- CYTH1 | c.688G>A p.E230K | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.433); catalogued as COSV100739257; called by muse, mutect2
- DCT | c.1477C>A p.L493I | Missense Mutation (SNP) | VAF 22/166 reads (13%) | SIFT tolerated (0.37); PolyPhen benign (0.01); catalogued as COSV65470385; called by muse, mutect2, varscan2
- DDR1 | c.205G>A p.G69R | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs920057612, COSV61327829; called by muse, mutect2, varscan2
- DIPK2A | c.349G>A p.E117K | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs745537687; called by muse, mutect2, varscan2
- DMRT1 | c.214C>T p.R72W | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101206647; called by muse, mutect2, varscan2
- DNAH10 | c.1336G>A p.E446K (on ENST00000409039; = p.E385K on NM_207437.3) | Missense Mutation (SNP) | VAF 32/287 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.104); catalogued as rs762584820, COSV68987560; called by muse, varscan2
- DNAH2 | c.10263G>A p.M3421I | Missense Mutation (SNP) | VAF 43/281 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.285); catalogued as rs1418134694; called by muse, mutect2, varscan2
- DNAH7 | c.6236C>A p.S2079Y | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV56778714; called by muse, mutect2
- DNAH9 | c.12703G>A p.E4235K | Missense Mutation (SNP) | VAF 13/133 reads (10%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.87); catalogued as rs764035063; called by muse, mutect2, varscan2
- DNMT1 | c.2505C>G p.I835M | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.026); catalogued as COSV61584347; called by mutect2, varscan2
- DTNA | c.1432G>A p.E478K | Missense Mutation (SNP) | VAF 29/201 reads (14%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.993); catalogued as COSV52015758; called by muse, mutect2, varscan2
- EFCAB6 | c.2020C>G p.Q674E | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); catalogued as rs751375957, COSV53058619; called by muse, mutect2, varscan2
- EP400 | c.2677C>T p.L893= | Splice Region (SNP) | VAF 91/198 reads (46%) | catalogued as rs773438145, COSV100202134; called by muse, mutect2, varscan2
- EXOC3L4 | c.1999C>G p.L667V | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs760213756; called by muse, mutect2, varscan2
- EXPH5 | c.357G>C p.M119I | Missense Mutation (SNP) | VAF 28/226 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.061); catalogued as COSV56201766; called by muse, mutect2, varscan2
- EXTL1 | c.2004G>T p.K668N | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs944544073; called by mutect2, varscan2
- FAM122A | c.625G>A p.E209K | Missense Mutation (SNP) | VAF 51/334 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV99598323; called by muse, mutect2, varscan2
- FAM167B | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.028); catalogued as COSV61111679; called by mutect2, varscan2
- FAM234A | c.143G>A p.R48Q | Missense Mutation (SNP) | VAF 19/156 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747976922; called by muse, mutect2, varscan2
- FBLN7 | c.514C>T p.Q172* | Nonsense Mutation (SNP) | VAF 26/127 reads (20%) | catalogued as rs371822789; called by muse, mutect2, varscan2
- FOXP4 | c.1886C>T p.P629L (on ENST00000307972 / NM_001012426.1; = p.P616L on NM_138457.3) | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.97); PolyPhen benign (0.003); catalogued as rs1386450589; called by muse, mutect2
- GHR | c.41G>A p.G14E | Missense Mutation (SNP) | VAF 47/285 reads (16%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.162); catalogued as COSV50126415; called by muse, mutect2, varscan2
- GLDC | c.2629G>A p.E877K | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.919); catalogued as rs765893483; called by muse, mutect2, varscan2
- GMPR | c.40G>A p.D14N | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs574231468; called by muse, mutect2, varscan2
- GOLGB1 | c.8764C>A p.Q2922K | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.547); catalogued as COSV61463182; called by muse, mutect2, varscan2
- GPR155 | c.733C>A p.L245I | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.487); catalogued as COSV55042451; called by muse, mutect2
- GSPT2 | c.1510C>G p.L504V | Missense Mutation (SNP) | VAF 42/275 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.105); catalogued as rs1557348977, COSV61213972; called by muse, mutect2, varscan2
- HNRNPU | c.2155C>T p.Q719* (on ENST00000283179; = p.Q781* on NM_004501.3) | Nonsense Mutation (SNP) | VAF 14/137 reads (10%) | catalogued as COSV51692210; called by muse, varscan2
- HOXA10 | c.1102G>A p.E368K | Missense Mutation (SNP) | VAF 20/133 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52228865; called by muse, varscan2
- ICAM5 | c.1960G>A p.V654M | Missense Mutation (SNP) | VAF 10/288 reads (3%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV55747601; called by muse, mutect2
- IFNA2 | c.241G>A p.E81K | Missense Mutation (SNP) | VAF 24/188 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV66505492; called by muse, mutect2, varscan2
- IGHV2-70 | c.170G>C p.W57S | Missense Mutation (SNP) | VAF 45/121 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as rs374376585; called by muse, varscan2
- IGHV2-70 | c.148A>C p.T50P | Missense Mutation (SNP) | VAF 42/104 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as rs373039668; called by muse, varscan2
- IL16 | c.2042G>A p.R681K | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs755679188; called by muse, mutect2, varscan2
- IL17RC | c.2221C>G p.R741G (on ENST00000295981 / NM_153461.4; = p.R655G on NM_032732.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/177 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1477967348; called by muse, mutect2, varscan2
- INSYN2A | c.1033G>A p.E345K | Missense Mutation (SNP) | VAF 21/135 reads (16%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.517); catalogued as COSV99726228; called by muse, mutect2, varscan2
- KAT6A | c.1840C>T p.L614F | Missense Mutation (SNP) | VAF 35/259 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55905383; called by muse, mutect2, varscan2
- KCNJ3 | c.206C>G p.S69W | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54533558, COSV99715872; called by muse, mutect2, varscan2
- KCTD19 | c.2048C>T p.S683L | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.003); catalogued as COSV100431186; called by muse, mutect2, varscan2
- KIAA1109 | c.7513C>T p.P2505S | Missense Mutation (SNP) | VAF 18/152 reads (12%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); catalogued as rs1214600785; called by muse, mutect2, varscan2
- KIF13A | c.3319G>A p.E1107K | Missense Mutation (SNP) | VAF 43/230 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.908); catalogued as COSV52450980; called by muse, mutect2, varscan2
- KPNA1 | c.1013C>G p.S338* | Nonsense Mutation (SNP) | VAF 17/121 reads (14%) | catalogued as COSV60269899; called by muse, mutect2, varscan2
- LAMA2 | c.1820C>T p.S607L | Missense Mutation (SNP) | VAF 20/152 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as rs558018507, COSV70351696; called by muse, mutect2, varscan2
- LSG1 | c.1031C>G p.S344C | Missense Mutation (SNP) | VAF 20/143 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.405); catalogued as rs764286053, COSV54569898; called by muse, mutect2, varscan2
- LUC7L2 | c.1162G>A p.E388K | Missense Mutation (SNP) | VAF 53/391 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.905); catalogued as rs761762656, COSV54925953; called by muse, mutect2, varscan2
- LY9 | c.297G>A p.M99I | Missense Mutation (SNP) | VAF 68/541 reads (13%) | SIFT tolerated (0.48); PolyPhen benign (0.041); catalogued as rs1175528221; called by muse, mutect2, varscan2
- MACF1 | c.8626C>T p.H2876Y | Missense Mutation (SNP) | VAF 14/97 reads (14%) | catalogued as rs375426522; called by muse, mutect2, varscan2
- MAN1B1 | c.172G>A p.E58K | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.041); catalogued as rs753503405, CM1312986; called by muse, mutect2, varscan2
- MAP1B | c.1699G>A p.E567K | Missense Mutation (SNP) | VAF 18/120 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.056); catalogued as COSV57095914; called by muse, mutect2, varscan2
- MAPKBP1 | c.3268G>A p.E1090K (on ENST00000456763 / NM_001128608.2; = p.E1084K on NM_014994.3) | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.993); catalogued as rs1486501458; called by muse, varscan2
- ME1 | c.613G>C p.D205H | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV63840513; called by mutect2, varscan2
- MFSD13A | c.585C>G p.F195L | Missense Mutation (SNP) | VAF 32/190 reads (17%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.863); catalogued as COSV53268258; called by muse, mutect2, varscan2
- MGAT4B | c.970C>T p.R324W | Missense Mutation (SNP) | VAF 22/160 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as rs1047960020, COSV52977482; called by muse, mutect2, varscan2
- MKX | c.112C>T p.H38Y | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.053); catalogued as COSV101008597; called by muse, mutect2, varscan2
- MRM2 | c.37C>T p.Q13* | Nonsense Mutation (SNP) | VAF 26/121 reads (21%) | catalogued as rs746259393; called by muse, mutect2, varscan2
- MTFR1 | c.700G>A p.E234K | Missense Mutation (SNP) | VAF 16/154 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.345); catalogued as COSV50952162; called by muse, mutect2, varscan2
- NBEA | c.6130C>G p.L2044V | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT tolerated (0.74); PolyPhen benign (0.003); catalogued as COSV59766991; called by muse, mutect2, varscan2
- NFE2 | c.271C>T p.H91Y | Missense Mutation (SNP) | VAF 21/153 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as rs1438920821, COSV56456627; called by muse, varscan2
- NLRX1 | c.878C>T p.S293F | Missense Mutation (SNP) | VAF 33/184 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99066761; called by muse, mutect2, varscan2
- NUP88 | c.652G>A p.E218K | Missense Mutation (SNP) | VAF 44/173 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); catalogued as rs201799531; called by muse, mutect2, varscan2
- OPN1LW | c.697G>A p.A233T | Missense Mutation (SNP) | VAF 129/362 reads (36%) | SIFT tolerated (0.36); PolyPhen benign (0.009); catalogued as rs781936473, CM045802, COSV100885039, COSV64049532; called by muse, mutect2, varscan2
- OR4D6 | c.347C>T p.S116F | Missense Mutation (SNP) | VAF 22/155 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.349); catalogued as COSV55659677; called by muse, mutect2, varscan2
- OR51G1 | c.275G>C p.R92T | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.806); catalogued as rs1453828638, COSV100429142, COSV58968441, COSV58969784; called by muse, mutect2, varscan2
- ORC3 | c.1417G>A p.E473K | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV57638845; called by muse, mutect2, varscan2
- OTUD1 | c.532G>A p.E178K | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as rs1451478607; called by muse, mutect2
- P2RY13 | c.289C>T p.P97S | Missense Mutation (SNP) | VAF 33/290 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99854446; called by muse, mutect2, varscan2
- PAK4 | c.1471C>T p.P491S | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.683); catalogued as rs748525257, COSV58945107; called by muse, mutect2, varscan2
- PARD3 | c.1283C>T p.S428L | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs141769427; called by muse, mutect2, varscan2
- PCDHB13 | c.608G>T p.R203L | Missense Mutation (SNP) | VAF 17/170 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as COSV53396416; called by muse, varscan2
- PDE6B | c.454G>A p.E152K | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs1302387853, COSV55330058; called by muse, mutect2, varscan2
- PKHD1L1 | c.9890G>C p.R3297T | Missense Mutation (SNP) | VAF 31/175 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.288); catalogued as rs201340021, COSV65736097, COSV65742581; called by muse, mutect2, varscan2
- PLBD1 | c.286G>A p.E96K | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.175); catalogued as COSV99554591; called by muse, mutect2, varscan2
- PLEC | c.3542C>G p.S1181C (on ENST00000322810 / NM_201380.4; = p.S1071C on NM_000445.5) | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.628); catalogued as COSV100517807; called by mutect2, varscan2
- PTBP3 | c.1315C>T p.R439* | Nonsense Mutation (SNP) | VAF 31/232 reads (13%) | catalogued as COSV57587192; called by muse, mutect2, varscan2
- RBMX | c.302G>C p.R101T | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.835); catalogued as COSV100284874; called by muse, mutect2, varscan2
- RPL17-C18orf32 | c.148G>A p.D50N | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.072); catalogued as COSV59087413; called by muse, mutect2
- RPS6KA4 | c.2081C>T p.S694F | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.522); catalogued as rs747011048, COSV53704628, COSV53705599; called by muse, mutect2, varscan2
- RPS6KA6 | c.118G>C p.E40Q | Missense Mutation (SNP) | VAF 14/118 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.027); catalogued as COSV53126345; called by muse, mutect2, varscan2
- SCP2D1 | c.450C>G p.F150L | Missense Mutation (SNP) | VAF 59/408 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.139); catalogued as COSV53857916; called by muse, mutect2, varscan2
- SEMA6A | c.2888C>A p.P963Q | Missense Mutation (SNP) | VAF 7/145 reads (5%) | SIFT tolerated (0.11); PolyPhen probably damaging (1); catalogued as COSV56709327; called by muse, mutect2
- SF3B3 | c.995C>G p.T332S | Missense Mutation (SNP) | VAF 96/262 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.838); catalogued as COSV100209881; called by muse, mutect2, varscan2
- SIPA1L3 | c.154G>A p.E52K | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated (0.43); PolyPhen benign (0.083); catalogued as rs753429177, COSV55917980; called by muse, mutect2, varscan2
- SIRPG | c.603G>C p.Q201H | Missense Mutation (SNP) | VAF 16/236 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs995344303, COSV53809933; called by muse, mutect2
- SLC25A29 | c.856G>A p.E286K (on ENST00000359232 / NM_001039355.3; = p.E220K on NM_152333.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.023); catalogued as rs1325289045; called by mutect2, varscan2
- SPAG17 | c.1956G>A p.M652I | Missense Mutation (SNP) | VAF 41/291 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV60456688; called by muse, varscan2
- SRSF1 | c.517C>T p.R173* | Nonsense Mutation (SNP) | VAF 26/244 reads (11%) | catalogued as COSV99365405; called by muse, mutect2, varscan2
- STAT3 | c.372+3G>A | Splice Region (SNP) | VAF 4/46 reads (9%) | catalogued as rs1391959003; called by muse, mutect2
- STK32B | c.1157G>C p.R386P | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV51497036; called by muse, mutect2, varscan2
- STYXL2 | c.2221G>A p.E741K | Missense Mutation (SNP) | VAF 24/144 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54806843; called by muse, varscan2
- TAMM41 | c.638G>A p.R213Q | Missense Mutation (SNP) | VAF 43/113 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0.351); catalogued as rs760435126; called by muse, mutect2, varscan2
- TGM7 | c.2074G>A p.E692K | Missense Mutation (SNP) | VAF 19/151 reads (13%) | SIFT tolerated (1); PolyPhen possibly damaging (0.889); catalogued as rs370200406; called by muse, mutect2, varscan2
- TMEM30B | c.827C>T p.A276V | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.098); catalogued as rs763302533; called by muse, mutect2, varscan2
- TNXB | c.10283C>G p.S3428W (on ENST00000647633; = p.S3181W on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756035213; called by muse, mutect2, varscan2
- TOGARAM1 | c.1940G>A p.R647Q | Missense Mutation (SNP) | VAF 35/183 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs759654991, COSV61887498; called by muse, mutect2, varscan2
- TPCN2 | c.733G>A p.D245N | Missense Mutation (SNP) | VAF 11/96 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0.018); catalogued as rs1260308010; called by muse, mutect2, varscan2
- TPCN2 | c.1587C>T p.G529= | Splice Region (SNP) | VAF 18/68 reads (26%) | catalogued as rs1174741889; called by muse, mutect2, varscan2
- TRIM49B | c.946C>G p.Q316E | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT tolerated (0.41); PolyPhen benign (0.024); catalogued as COSV60320546; called by muse, mutect2, varscan2
- TRIP11 | c.755G>A p.R252Q | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.118); catalogued as rs766379562, COSV50917120; called by muse, mutect2, varscan2
- TSPYL1 | c.931G>A p.E311K | Missense Mutation (SNP) | VAF 33/234 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV100889630; called by muse, mutect2, varscan2
- TTN | c.16000G>T p.E5334* (on ENST00000591111; = p.E4407* on NM_133378.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 21/128 reads (16%) | catalogued as COSV59966690; called by muse, mutect2, varscan2
- WWP2 | c.1028G>A p.R343Q | Missense Mutation (SNP) | VAF 17/127 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.806); catalogued as rs367812535; called by muse, mutect2, varscan2
- YTHDC2 | c.526C>T p.Q176* | Nonsense Mutation (SNP) | VAF 18/163 reads (11%) | catalogued as COSV50749994; called by muse, mutect2, varscan2
- ZDBF2 | c.6377C>T p.S2126F | Missense Mutation (SNP) | VAF 54/197 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.098); catalogued as rs1559163082, COSV65629755; called by muse, mutect2, varscan2
- ZFHX3 | c.1670C>T p.S557F | Missense Mutation (SNP) | VAF 44/117 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.624); catalogued as COSV51714212; called by muse, mutect2, varscan2
- ZGRF1 | c.5256G>A p.M1752I | Missense Mutation (SNP) | VAF 25/127 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.088); catalogued as rs1560748745, COSV71394035; called by muse, mutect2, varscan2
- ZNF107 | c.700C>A p.Q234K | Missense Mutation (SNP) | VAF 19/122 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.108); catalogued as COSV61331367; called by muse, mutect2, varscan2
- ZNF814 | c.2431G>A p.E811K | Missense Mutation (SNP) | VAF 20/127 reads (16%) | SIFT tolerated (0.97); PolyPhen benign (0.015); catalogued as rs1289722293, COSV101457268; called by muse, mutect2, varscan2
- ZSWIM2 | c.1439C>G p.S480* | Nonsense Mutation (SNP) | VAF 7/49 reads (14%) | catalogued as COSV54575505; called by muse, mutect2, varscan2
- ABCA12 | c.7181C>G p.T2394R (on ENST00000272895 / NM_173076.3; = p.T2076R on NM_015657.3) | Missense Mutation (SNP) | VAF 25/115 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ABCA5 | c.1979G>A p.R660K | Missense Mutation (SNP) | VAF 42/267 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.213); called by muse, mutect2, varscan2
- ABCE1 | c.1059G>A p.M353I | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- AC018709.1 | c.185G>A p.R62K | Missense Mutation (SNP) | VAF 19/131 reads (15%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADAMTS16 | c.109C>T p.P37S | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.003); called by muse, mutect2
- ADAT3 | c.974G>A p.G325D | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADGRF2 | c.857C>T p.S286L (on ENST00000296862 / NM_001368115.2; = p.S218L on NM_153839.7) | Missense Mutation (SNP) | VAF 33/184 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- ADGRV1 | c.16705G>C p.E5569Q | Missense Mutation (SNP) | VAF 28/263 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- AFF1 | c.1850C>T p.S617L | Missense Mutation (SNP) | VAF 24/152 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, varscan2
- AFF4 | c.1327G>A p.E443K | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- AKAP6 | c.899C>T p.S300L | Missense Mutation (SNP) | VAF 13/118 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- AMER1 | c.1715A>G p.E572G | Missense Mutation (SNP) | VAF 29/181 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- ANKRD30B | c.1537C>G p.Q513E | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.388); called by muse, mutect2, varscan2
- ARHGAP31 | c.1234G>A p.D412N | Missense Mutation (SNP) | VAF 29/159 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- ARHGAP31 | c.1609G>C p.E537Q | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- ARHGAP4 | c.1615G>T p.E539* | Nonsense Mutation (SNP) | VAF 14/135 reads (10%) | called by muse, mutect2, varscan2
- ASAP1 | c.3346A>G p.K1116E | Missense Mutation (SNP) | VAF 55/210 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- ASCC3 | c.3142G>A p.G1048R | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ATF6B | c.1087G>A p.D363N | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.818); called by muse, mutect2, varscan2
- ATP10A | c.2062G>A p.E688K | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0.043); called by muse, mutect2
- ATRNL1 | c.551C>G p.S184C | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- BICRA | c.4382A>C p.D1461A | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.025); called by muse, varscan2
- BICRA | c.4427A>T p.K1476M | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- BPIFA1 | c.685G>A p.E229K | Missense Mutation (SNP) | VAF 26/134 reads (19%) | SIFT tolerated (0.56); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- BRWD1 | c.6473C>T p.S2158L | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.702); called by muse, mutect2, varscan2
- BUD23 | c.617C>A p.S206Y | Missense Mutation (SNP) | VAF 20/111 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- C1orf94 | c.1313A>G p.Y438C (on ENST00000488417 / NM_001134734.2; = p.Y248C on NM_032884.5) | Missense Mutation (SNP) | VAF 17/157 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- CATSPER1 | c.22G>C p.E8Q | Missense Mutation (SNP) | VAF 18/144 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.231); called by muse, mutect2, varscan2
- CCDC168 | c.5362C>G p.Q1788E | Missense Mutation (SNP) | VAF 15/137 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- CDKAL1 | c.876G>A p.M292I | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CDON | c.17G>A p.G6E | Missense Mutation (SNP) | VAF 30/227 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.344); called by muse, varscan2
- CENPE | c.5323G>A p.E1775K | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.917); called by muse, mutect2
- CEP135 | c.1278G>C p.R426S | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- CHCHD6 | c.487G>A p.E163K | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- CLBA1 | c.352G>C p.E118Q | Missense Mutation (SNP) | VAF 80/484 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.432); called by muse, mutect2, varscan2
- CLCN5 | c.280T>G p.F94V | Missense Mutation (SNP) | VAF 31/204 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); called by muse, mutect2, varscan2
- CLDN8 | c.142G>A p.E48K | Missense Mutation (SNP) | VAF 38/254 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- COL14A1 | c.1043C>T p.S348L | Missense Mutation (SNP) | VAF 15/115 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- CRAT | c.670C>G p.L224V | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.374); called by muse, varscan2
- CRYBG1 | c.4394T>G p.I1465R | Missense Mutation (SNP) | VAF 20/170 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.741); called by muse, mutect2, varscan2
- CTNNA2 | c.2026C>T p.P676S | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2
- CUBN | c.7955C>T p.S2652L | Missense Mutation (SNP) | VAF 34/248 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.125); called by muse, varscan2
- CUX2 | c.3046G>A p.E1016K | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- CYP2R1 | c.856C>G p.Q286E | Missense Mutation (SNP) | VAF 21/157 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CYP3A7 | c.835C>T p.Q279* | Nonsense Mutation (SNP) | VAF 22/125 reads (18%) | called by muse, mutect2, varscan2
- DACH1 | c.2144C>T p.S715L (on ENST00000619232 / NM_001366712.1; = p.S461L on NM_004392.6) | Missense Mutation (SNP) | VAF 34/239 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.468); called by muse, varscan2
- DDHD1 | c.121G>A p.E41K (on ENST00000323669; = p.E272K on NM_030637.3) | Missense Mutation (SNP) | VAF 73/283 reads (26%) | SIFT tolerated (0.48); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DDX50 | c.1306G>A p.E436K | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- DGKI | c.1813A>G p.I605V | Missense Mutation (SNP) | VAF 6/113 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.241); called by muse, mutect2
- DHRS7 | c.983C>G p.S328C | Missense Mutation (SNP) | VAF 86/209 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DHX36 | c.1805G>C p.R602P | Missense Mutation (SNP) | VAF 59/433 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DIDO1 | c.5527G>C p.E1843Q | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- DIP2A | c.2725C>G p.H909D | Missense Mutation (SNP) | VAF 24/136 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.802); called by muse, mutect2, varscan2
- DLK2 | c.907G>C p.G303R | Missense Mutation (SNP) | VAF 36/166 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DNM1L | c.334G>C p.E112Q | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.268); called by mutect2, varscan2
- DNTT | c.217C>A p.H73N | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- EFCAB8 | c.3403C>T p.Q1135* | Nonsense Mutation (SNP) | VAF 8/69 reads (12%) | called by muse, mutect2, varscan2
- EHMT1 | c.434C>T p.S145F | Missense Mutation (SNP) | VAF 13/141 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.347); called by muse, mutect2
- EIF5 | c.634C>G p.Q212E | Missense Mutation (SNP) | VAF 16/155 reads (10%) | SIFT tolerated (0.37); PolyPhen benign (0.283); called by muse, mutect2, varscan2
- EN1 | c.662C>T p.S221L | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.236); called by muse, mutect2
- EPAS1 | c.510G>A p.M170I | Missense Mutation (SNP) | VAF 29/149 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- ERCC6L2 | c.1723G>A p.D575N | Missense Mutation (SNP) | VAF 14/104 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- EXOSC10 | c.87C>A p.F29L | Missense Mutation (SNP) | VAF 14/121 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.297); called by muse, mutect2, varscan2
- FANCB | c.1396_1399del p.D466Ifs*8 | Frame Shift Del (DEL) | VAF 7/46 reads (15%) | called by mutect2, pindel, varscan2
- FAT3 | c.865G>A p.D289N | Missense Mutation (SNP) | VAF 44/244 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FEM1C | c.787C>T p.L263F | Missense Mutation (SNP) | VAF 97/353 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.764); called by muse, mutect2, varscan2
- FGGY | c.202-1G>C p.X68_splice | Splice Site (SNP) | VAF 16/73 reads (22%) | called by muse, mutect2, varscan2
- FREM2 | c.3521C>T p.S1174L | Missense Mutation (SNP) | VAF 43/229 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FSD1L | c.345G>C p.Q115H (on ENST00000481272 / NM_001145313.3; = p.Q83H on NM_031919.5) | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by mutect2, varscan2
- FTMT | c.556G>A p.D186N | Missense Mutation (SNP) | VAF 16/147 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- FZD7 | c.634C>T p.R212C | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.513); called by muse, varscan2
- GABRP | c.126G>C p.E42D | Missense Mutation (SNP) | VAF 10/103 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GALNT6 | c.1369-1G>C p.X457_splice | Splice Site (SNP) | VAF 9/87 reads (10%) | called by muse, mutect2, varscan2
- GARS1 | c.1287C>G p.F429L | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); called by mutect2, varscan2
- GCNT1 | c.400G>A p.E134K | Missense Mutation (SNP) | VAF 14/176 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.841); called by muse, mutect2
- GDE1 | c.237G>C p.E79D | Missense Mutation (SNP) | VAF 20/108 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- GFY | c.298G>A p.E100K | Missense Mutation (SNP) | VAF 66/239 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.031); called by muse, varscan2
- GLDN | c.1042G>A p.E348K | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- GPATCH8 | c.2464G>A p.D822N | Missense Mutation (SNP) | VAF 27/234 reads (12%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- GPRC5D | c.919G>A p.E307K | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- HAUS6 | c.8C>T p.S3L | Missense Mutation (SNP) | VAF 26/143 reads (18%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- HDAC7 | c.2334C>T p.F778= (on ENST00000427332; = p.F817= on NM_015401.5 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 5/39 reads (13%) | called by muse, mutect2
- HPS3 | c.657G>C p.E219D | Missense Mutation (SNP) | VAF 58/391 reads (15%) | SIFT tolerated (0.44); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- HTATSF1 | c.85G>A p.D29N | Missense Mutation (SNP) | VAF 37/156 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- IFNA2 | c.402G>A p.M134I | Missense Mutation (SNP) | VAF 35/242 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- IRX4 | c.1537G>A p.G513S | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.003); called by muse, mutect2
- JHY | c.435A>T p.E145D | Missense Mutation (SNP) | VAF 13/145 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.027); called by muse, mutect2
- KATNIP | c.4732G>C p.D1578H | Missense Mutation (SNP) | VAF 27/165 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KAZN | c.1148T>G p.M383R | Missense Mutation (SNP) | VAF 82/200 reads (41%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- KBTBD6 | c.31C>T p.R11C | Missense Mutation (SNP) | VAF 53/113 reads (47%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- KDM1A | c.574G>C p.E192Q | Missense Mutation (SNP) | VAF 36/237 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KIAA0319L | c.1295-1G>T p.X432_splice | Splice Site (SNP) | VAF 25/151 reads (17%) | called by muse, mutect2, varscan2
- KISS1 | c.398G>A p.R133K | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.83); PolyPhen benign (0.001); called by muse, varscan2
- KNL1 | c.5261C>G p.S1754C (on ENST00000346991 / NM_170589.5; = p.S1728C on NM_144508.5) | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- LAMC2 | c.2645C>G p.S882* | Nonsense Mutation (SNP) | VAF 36/234 reads (15%) | called by muse, mutect2, varscan2
- LGALSL | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MANF | c.415G>C p.E139Q | Missense Mutation (SNP) | VAF 21/135 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.719); called by muse, mutect2, varscan2
- MAST2 | c.491G>A p.R164K | Missense Mutation (SNP) | VAF 22/151 reads (15%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- MATN2 | c.1453G>A p.V485M | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- MCF2L2 | c.2305C>G p.L769V | Missense Mutation (SNP) | VAF 22/128 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MDC1 | c.2464G>T p.E822* | Nonsense Mutation (SNP) | VAF 33/259 reads (13%) | called by muse, mutect2, varscan2
- MED14 | c.3436C>G p.R1146G | Missense Mutation (SNP) | VAF 8/93 reads (9%) | SIFT tolerated (0.47); PolyPhen benign (0.028); called by muse, mutect2
- METAP2 | c.712G>A p.D238N | Missense Mutation (SNP) | VAF 17/121 reads (14%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- MMD | c.17G>A p.R6Q | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- MORF4L1 | c.61C>T p.H21Y | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- MORN1 | c.908C>A p.A303E | Missense Mutation (SNP) | VAF 8/192 reads (4%) | SIFT tolerated (0.82); PolyPhen benign (0.001); called by muse, mutect2
- MUC12 | c.16339G>A p.E5447K (on ENST00000379442; = p.E5304K on NM_001164462.1) | Missense Mutation (SNP) | VAF 28/199 reads (14%) | SIFT deleterious, low confidence (0); called by muse, varscan2
- NAV2 | c.4448C>A p.S1483Y (on ENST00000396087 / NM_001244963.2; = p.S1460Y on NM_145117.5) | Missense Mutation (SNP) | VAF 24/164 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- NAV2 | c.4786G>A p.D1596N (on ENST00000396087 / NM_001244963.2; = p.D1573N on NM_145117.5) | Missense Mutation (SNP) | VAF 24/207 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- NAXD | c.145G>A p.D49N | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- NECTIN2 | c.727G>A p.E243K | Missense Mutation (SNP) | VAF 38/297 reads (13%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.739); called by muse, mutect2, varscan2
- NOM1 | c.538G>A p.E180K | Missense Mutation (SNP) | VAF 25/163 reads (15%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- NRCAM | c.3645G>A p.M1215I (on ENST00000379028 / NM_001371124.1; = p.M1094I on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/147 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.613); called by muse, mutect2, varscan2
- ODF3B | c.371C>T p.T124I | Missense Mutation (SNP) | VAF 28/171 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.66); called by muse, mutect2, varscan2
- OGFOD3 | c.329G>A p.R110K | Missense Mutation (SNP) | VAF 21/140 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- OLFML2A | c.544G>A p.E182K | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- OPTN | c.572C>T p.S191L | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- OR2AK2 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 31/207 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.076); called by muse, varscan2
- OR8I2 | c.672C>G p.I224M | Missense Mutation (SNP) | VAF 50/433 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); called by muse, mutect2, varscan2
- PAK1 | c.268G>A p.D90N | Missense Mutation (SNP) | VAF 26/224 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.437); called by muse, mutect2, varscan2
- PANK4 | c.897C>G p.I299M | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PAOX | c.193G>A p.E65K | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PAX4 | c.129C>G p.I43M | Missense Mutation (SNP) | VAF 17/163 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PCDH12 | c.3474G>A p.M1158I | Missense Mutation (SNP) | VAF 26/144 reads (18%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- PCDH7 | c.1636G>C p.E546Q | Missense Mutation (SNP) | VAF 128/306 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- PCDH9 | c.194G>A p.R65K | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PCNT | c.4249G>C p.E1417Q | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.879); called by muse, mutect2
- PDE1A | c.216-1G>A p.X72_splice | Splice Site (SNP) | VAF 23/83 reads (28%) | called by muse, mutect2, varscan2
- PDE6B | c.886G>C p.E296Q | Missense Mutation (SNP) | VAF 61/157 reads (39%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- PHF12 | c.2628G>C p.K876N | Missense Mutation (SNP) | VAF 18/118 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PHLDB2 | c.3267G>C p.Q1089H (on ENST00000393925 / NM_001134439.2; = p.Q1046H on NM_145753.2) | Missense Mutation (SNP) | VAF 30/200 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PLEKHG3 | c.2579G>T p.S860I (on ENST00000394691; = p.S916I on NM_001308147.2) | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.571); called by muse, mutect2, varscan2
- POLR1C | c.25G>A p.E9K | Missense Mutation (SNP) | VAF 30/142 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- POM121C | c.812C>T p.S271L (on ENST00000607367; = p.S29L on NM_001099415.3) | Missense Mutation (SNP) | VAF 39/265 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.777); called by muse, mutect2, varscan2
- PROC | c.251C>G p.S84C | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- PRR32 | c.424G>A p.G142R | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- PRRC2C | c.1678G>A p.E560K (on ENST00000367742; = p.E558K on NM_015172.4) | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- PTPRS | c.4192G>A p.E1398K | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- RAD52 | c.183G>C p.Q61H | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- RARS2 | c.55C>T p.L19F | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT tolerated (0.49); PolyPhen benign (0.226); called by mutect2, varscan2
- REV3L | c.1526G>A p.W509* | Nonsense Mutation (SNP) | VAF 22/151 reads (15%) | called by muse, mutect2, varscan2
- RIOX1 | c.676G>A p.E226K | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- RLIM | c.362C>G p.S121C | Missense Mutation (SNP) | VAF 24/144 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RNF180 | c.1048G>C p.E350Q | Missense Mutation (SNP) | VAF 49/143 reads (34%) | SIFT tolerated (0.68); PolyPhen benign (0.069); called by mutect2, varscan2
- RREB1 | c.3664G>C p.E1222Q | Missense Mutation (SNP) | VAF 30/154 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- RSF1 | c.4039G>A p.E1347K | Missense Mutation (SNP) | VAF 37/229 reads (16%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- RSF1 | c.2699C>T p.P900L | Missense Mutation (SNP) | VAF 30/200 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- RYR3 | c.4178G>C p.G1393A | Missense Mutation (SNP) | VAF 23/188 reads (12%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SAMD1 | c.637-1G>A p.X213_splice | Splice Site (SNP) | VAF 17/99 reads (17%) | called by muse, mutect2, varscan2
- SCML4 | c.821C>G p.S274C | Missense Mutation (SNP) | VAF 22/122 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- SEC31B | c.446G>A p.W149* | Nonsense Mutation (SNP) | VAF 10/89 reads (11%) | called by muse, mutect2, varscan2
- SEPTIN1 | c.700-3G>A | Splice Region (SNP) | VAF 14/120 reads (12%) | called by mutect2, varscan2
- SESN1 | c.682G>A p.D228N (on ENST00000356644 / NM_001199933.1; = p.D287N on NM_014454.3) | Missense Mutation (SNP) | VAF 26/187 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- SLC16A12 | c.1463G>A p.G488E | Missense Mutation (SNP) | VAF 22/148 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC2A5 | c.294-1G>A p.X98_splice | Splice Site (SNP) | VAF 30/215 reads (14%) | called by muse, mutect2, varscan2
- SLC45A4 | c.3G>C p.M1? | Translation Start Site (SNP) | VAF 13/114 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SLC9A8 | c.827C>G p.T276S | Missense Mutation (SNP) | VAF 23/169 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- SLITRK3 | c.2540C>A p.S847* | Nonsense Mutation (SNP) | VAF 47/383 reads (12%) | called by muse, mutect2, varscan2
- SMC4 | c.2455G>C p.E819Q | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.381); called by muse, mutect2, varscan2
- SMTN | c.366G>C p.E122D | Missense Mutation (SNP) | VAF 17/122 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.306); called by muse, mutect2, varscan2
- SORBS1 | c.3533G>C p.G1178A | Missense Mutation (SNP) | VAF 26/178 reads (15%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- SOX6 | c.631G>A p.E211K | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- SPAG16 | c.1297G>C p.E433Q | Missense Mutation (SNP) | VAF 20/171 reads (12%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- SPATA5 | c.2165C>A p.S722Y | Missense Mutation (SNP) | VAF 23/352 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- SPG11 | c.94C>T p.P32S | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SSBP2 | c.779-3C>T | Splice Region (SNP) | VAF 10/45 reads (22%) | called by muse, mutect2, varscan2
- STXBP5L | c.190-1G>A p.X64_splice | Splice Site (SNP) | VAF 39/264 reads (15%) | called by muse, mutect2, varscan2
- SUGP1 | c.123G>C p.Q41H | Missense Mutation (SNP) | VAF 30/181 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- TACC2 | c.5848G>A p.E1950K (on ENST00000334433; = p.E28K on NM_006997.4) | Missense Mutation (SNP) | VAF 66/319 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TAS1R3 | c.1981G>A p.E661K | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT tolerated (0.8); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TBC1D16 | c.601G>C p.E201Q | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TEX13C | c.192G>C p.K64N | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TEX15 | c.319G>A p.E107K (on ENST00000638951; = p.E103K on NM_001350162.2) | Missense Mutation (SNP) | VAF 21/118 reads (18%) | SIFT tolerated (0.33); called by muse, mutect2, varscan2
- TMBIM4 | c.663C>G p.I221M | Missense Mutation (SNP) | VAF 51/389 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.615); called by muse, mutect2, varscan2
- TMEM52B | c.54+2T>C p.X18_splice (on ENST00000381923 / NM_001079815.1; = p.X13_splice on NM_153022.4) | Splice Site (SNP) | VAF 67/160 reads (42%) | called by muse, varscan2
- TNFAIP8 | c.430C>G p.Q144E | Missense Mutation (SNP) | VAF 46/434 reads (11%) | SIFT tolerated (0.8); PolyPhen benign (0.127); called by muse, varscan2
- TRIM66 | c.3023A>T p.E1008V | Missense Mutation (SNP) | VAF 18/129 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- TSPOAP1 | c.4835C>A p.P1612H | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TTC25 | c.134G>C p.G45A | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- TUBGCP5 | c.1020G>C p.E340D | Missense Mutation (SNP) | VAF 30/191 reads (16%) | SIFT tolerated (0.35); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- UNC80 | c.5578G>A p.D1860N | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by mutect2, varscan2
- USH2A | c.3601C>T p.H1201Y | Missense Mutation (SNP) | VAF 23/149 reads (15%) | SIFT tolerated (0.51); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- VSIG10L | c.1597G>A p.E533K | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- WDHD1 | c.451C>G p.L151V | Missense Mutation (SNP) | VAF 22/142 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.281); called by muse, mutect2, varscan2
- WDR24 | c.1879G>T p.E627* (on ENST00000248142; = p.E497* on NM_032259.4) | Nonsense Mutation (SNP) | VAF 37/181 reads (20%) | called by muse, mutect2, varscan2
- WDR33 | c.1733C>T p.S578F | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- WDR81 | c.4903C>T p.H1635Y (on ENST00000409644 / NM_001163809.2; = p.H584Y on NM_152348.4) | Missense Mutation (SNP) | VAF 44/231 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- WWP2 | c.190G>C p.E64Q | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT tolerated (0.37); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- ZBP1 | c.719C>G p.S240* | Nonsense Mutation (SNP) | VAF 8/88 reads (9%) | called by muse, mutect2
- ZBTB6 | c.371C>T p.S124L | Missense Mutation (SNP) | VAF 31/187 reads (17%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- ZC3H6 | c.3122C>T p.S1041L | Missense Mutation (SNP) | VAF 27/177 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- ZDHHC24 | c.31G>A p.D11N | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZFP36L2 | c.914C>T p.S305F | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.74); PolyPhen possibly damaging (0.795); called by muse, mutect2, varscan2
- ZNF107 | c.1507_1517del p.K503Sfs*7 | Frame Shift Del (DEL) | VAF 10/85 reads (12%) | called by mutect2, pindel
- ZNF112 | c.926G>C p.R309T (on ENST00000337401 / NM_001083335.2; = p.R303T on NM_013380.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT tolerated (0.75); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ZNF165 | c.1243C>T p.L415F | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- ZNF217 | c.1841T>C p.V614A | Missense Mutation (SNP) | VAF 46/180 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF234 | c.921C>A p.C307* | Nonsense Mutation (SNP) | VAF 82/210 reads (39%) | called by muse, mutect2, varscan2
- ZNF354B | c.614C>G p.S205* | Nonsense Mutation (SNP) | VAF 8/63 reads (13%) | called by muse, mutect2, varscan2
- ZNF43 | c.952G>A p.E318K | Missense Mutation (SNP) | VAF 35/107 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.633); called by muse, mutect2, varscan2
- ZNF446 | c.712+3G>A | Splice Region (SNP) | VAF 16/101 reads (16%) | called by muse, mutect2, varscan2
- ZNF577 | c.141G>C p.L47F | Missense Mutation (SNP) | VAF 33/312 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZNF586 | c.205G>A p.E69K | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF596 | c.481C>T p.H161Y | Missense Mutation (SNP) | VAF 29/160 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ZXDA | c.712G>A p.A238T | Missense Mutation (SNP) | VAF 17/28 reads (61%) | SIFT tolerated (0.16); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ABRAXAS2 | c.120C>T p.I40= | Silent (SNP) | VAF 12/118 reads (10%) | called by muse, mutect2, varscan2
- ACAP3 | c.1230G>A p.Q410= | Silent (SNP) | VAF 17/92 reads (18%) | called by muse, mutect2, varscan2
- ADAR | c.1389G>A p.L463= | Silent (SNP) | VAF 10/113 reads (9%) | catalogued as COSV52718227; called by muse, mutect2
- ADGRE1 | c.630G>A p.L210= | Silent (SNP) | VAF 10/57 reads (18%) | catalogued as rs1186876842; called by muse, mutect2, varscan2
- ADGRG5 | c.51G>A p.Q17= | Silent (SNP) | VAF 13/96 reads (14%) | called by muse, mutect2, varscan2
- AHNAK2 | c.6258C>G p.L2086= | Silent (SNP) | VAF 16/56 reads (29%) | called by muse, mutect2, varscan2
- ANK3 | c.2052C>T p.L684= | Silent (SNP) | VAF 12/85 reads (14%) | catalogued as rs189921774; called by muse, mutect2, varscan2
- ANKLE1 | c.48C>T p.L16= | Silent (SNP) | VAF 11/68 reads (16%) | called by muse, mutect2, varscan2
- APH1A | c.729C>G p.L243= | Silent (SNP) | VAF 42/119 reads (35%) | called by muse, mutect2, varscan2
- ARID3C | c.621C>T p.L207= | Silent (SNP) | VAF 15/133 reads (11%) | called by muse, mutect2, varscan2
- ARL10 | c.9G>T p.P3= | Silent (SNP) | VAF 9/38 reads (24%) | called by mutect2, varscan2
- ARMH4 | c.981C>G p.T327= | Silent (SNP) | VAF 16/232 reads (7%) | catalogued as rs763551388, COSV99958970; called by muse, mutect2
- BMPR1B | c.57C>T p.L19= | Silent (SNP) | VAF 19/78 reads (24%) | catalogued as rs908075496; called by muse, mutect2, varscan2
- C1orf167 | c.3579C>T p.L1193= | Silent (SNP) | VAF 33/83 reads (40%) | called by muse, mutect2, varscan2
- C2CD4D | c.171C>T p.L57= | Silent (SNP) | VAF 6/28 reads (21%) | called by muse, mutect2, varscan2
- CACNA1A | c.609C>G p.L203= | Silent (SNP) | VAF 25/126 reads (20%) | called by muse, mutect2, varscan2
- CADM1 | c.1104G>C p.S368= | Silent (SNP) | VAF 29/163 reads (18%) | catalogued as COSV59009621; called by muse, mutect2, varscan2
- CDK5RAP2 | c.162C>T p.P54= | Silent (SNP) | VAF 22/178 reads (12%) | catalogued as rs372350373; called by muse, varscan2
- CEBPB | c.478C>T p.L160= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as rs1400662874; called by muse, mutect2
- CEP295 | c.18G>A p.V6= | Silent (SNP) | VAF 15/153 reads (10%) | called by muse, mutect2, varscan2
- CHSY3 | c.561C>T p.R187= | Silent (SNP) | VAF 12/97 reads (12%) | catalogued as rs1279535909; called by muse, mutect2, varscan2
- CLASP2 | c.3138C>T p.V1046= (on ENST00000359576; = p.V1045= on NM_015097.3 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 42/276 reads (15%) | catalogued as COSV56286087; called by muse, varscan2
- CLCN4 | c.2019C>A p.I673= | Silent (SNP) | VAF 17/161 reads (11%) | called by muse, mutect2, varscan2
- COPB2 | c.1131C>T p.I377= | Silent (SNP) | VAF 22/267 reads (8%) | called by muse, mutect2
- COQ7 | c.228G>C p.R76= | Silent (SNP) | VAF 11/58 reads (19%) | catalogued as COSV58981527; called by muse, mutect2
- CYP26C1 | c.145C>T p.L49= | Silent (SNP) | VAF 13/48 reads (27%) | called by muse, mutect2, varscan2
- CYP4F2 | c.1467C>T p.F489= | Silent (SNP) | VAF 11/66 reads (17%) | catalogued as rs776263021; called by mutect2, varscan2
- DCDC1 | c.5100C>G p.L1700= (on ENST00000597505 / NM_001367979.1; = p.L807= on NM_020869.3) | Silent (SNP) | VAF 8/111 reads (7%) | catalogued as COSV100360775; called by muse, mutect2
- DENND2D | c.1305C>A p.I435= | Silent (SNP) | VAF 10/83 reads (12%) | catalogued as COSV100718732; called by muse, mutect2, varscan2
- DHX30 | c.2418C>T p.F806= (on ENST00000445061 / NM_138615.3; = p.F767= on NM_014966.3) | Silent (SNP) | VAF 40/238 reads (17%) | called by muse, mutect2, varscan2
- DHX40 | c.654C>T p.L218= | Silent (SNP) | VAF 36/273 reads (13%) | called by muse, varscan2
- DIAPH2 | c.114G>A p.T38= | Silent (SNP) | VAF 18/135 reads (13%) | called by muse, mutect2, varscan2
- DMPK | c.171C>T p.I57= | Silent (SNP) | VAF 15/93 reads (16%) | catalogued as rs1311706791; called by muse, mutect2, varscan2
- DSCAM | c.4743C>G p.V1581= | Silent (SNP) | VAF 18/144 reads (13%) | called by muse, mutect2, varscan2
- EDDM3B | c.432T>G p.P144= | Silent (SNP) | VAF 11/59 reads (19%) | called by muse, mutect2, varscan2
- EDEM2 | c.675C>G p.L225= | Silent (SNP) | VAF 3/22 reads (14%) | catalogued as COSV65712888; called by muse, mutect2
- EFCAB8 | c.1179C>T p.F393= | Silent (SNP) | VAF 11/53 reads (21%) | called by muse, mutect2, varscan2
- EIF1AD | c.207C>G p.L69= | Silent (SNP) | VAF 4/29 reads (14%) | catalogued as COSV100381376; called by mutect2, varscan2
- EML6 | c.4260C>G p.L1420= | Silent (SNP) | VAF 25/193 reads (13%) | catalogued as rs1383779817, COSV62864878; called by muse, mutect2, varscan2
- ETF1 | c.48G>A p.K16= | Silent (SNP) | VAF 35/167 reads (21%) | catalogued as rs200278268; called by muse, mutect2, varscan2
- EVI5L | c.2136C>T p.F712= | Silent (SNP) | VAF 7/36 reads (19%) | called by muse, mutect2, varscan2
- FAM117B | c.1284G>A p.E428= | Silent (SNP) | VAF 13/141 reads (9%) | called by muse, mutect2
- FAM83G | c.42G>A p.V14= | Silent (SNP) | VAF 16/114 reads (14%) | catalogued as COSV100524862; called by muse, mutect2, varscan2
- FAT2 | c.4938G>A p.V1646= | Silent (SNP) | VAF 17/155 reads (11%) | called by muse, mutect2, varscan2
- FGD4 | c.1284G>A p.Q428= | Silent (SNP) | VAF 26/206 reads (13%) | called by muse, mutect2
- FOXA1 | c.15G>A p.V5= | Silent (SNP) | VAF 56/449 reads (12%) | catalogued as rs777922164, COSV51645842; called by muse, mutect2, varscan2
- FRMD1 | c.498G>A p.L166= | Silent (SNP) | VAF 10/65 reads (15%) | catalogued as rs1361852597; called by muse, mutect2, varscan2
- GCGR | c.558G>A p.L186= | Silent (SNP) | VAF 22/156 reads (14%) | catalogued as rs1472968426; called by muse, mutect2, varscan2
- GDF11 | c.285C>T p.I95= | Silent (SNP) | VAF 17/100 reads (17%) | called by muse, mutect2, varscan2
- GIGYF2 | c.3789G>A p.K1263= | Silent (SNP) | VAF 32/210 reads (15%) | called by muse, mutect2, varscan2
- GLI2 | c.2016G>A p.G672= (on ENST00000361492 / NM_001374353.1; = p.G689= on NM_005270.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 15/126 reads (12%) | catalogued as COSV58051238, COSV58052541; called by muse, mutect2, varscan2
- H4C13 | c.311G>A p.*104= | Silent (SNP) | VAF 34/202 reads (17%) | catalogued as COSV100138001, COSV60695004; called by muse, mutect2, varscan2
- HADHA | c.102T>G p.A34= | Silent (SNP) | VAF 19/48 reads (40%) | called by muse, mutect2, varscan2
- HEATR3 | c.1059G>A p.L353= | Silent (SNP) | VAF 26/153 reads (17%) | catalogued as rs532845983; called by muse, mutect2, varscan2
- HIF1AN | c.75C>G p.P25= | Silent (SNP) | VAF 14/116 reads (12%) | called by muse, mutect2, varscan2
- HSD17B13 | c.78C>T p.F26= | Silent (SNP) | VAF 20/158 reads (13%) | catalogued as COSV100143100; called by muse, varscan2
- HSD17B6 | c.747C>T p.I249= | Silent (SNP) | VAF 24/162 reads (15%) | catalogued as COSV59108546; called by muse, mutect2, varscan2
- IARS2 | c.165G>A p.S55= | Silent (SNP) | VAF 35/182 reads (19%) | called by muse, mutect2, varscan2
- ICE2 | c.426G>A p.V142= | Silent (SNP) | VAF 5/38 reads (13%) | catalogued as rs1274303680; called by muse, mutect2, varscan2
- IGDCC3 | c.519G>A p.E173= | Silent (SNP) | VAF 25/197 reads (13%) | called by muse, mutect2, varscan2
- IGHV2-70 | c.156A>C p.G52= | Silent (SNP) | VAF 38/101 reads (38%) | catalogued as rs1232476476; called by muse, varscan2
- ITPA | c.396C>T p.F132= | Silent (SNP) | VAF 15/125 reads (12%) | catalogued as rs756108585; called by muse, mutect2, varscan2
- ITPR2 | c.2127C>T p.I709= | Silent (SNP) | VAF 32/192 reads (17%) | called by muse, mutect2, varscan2
- JMJD4 | c.843C>G p.L281= | Silent (SNP) | VAF 9/85 reads (11%) | catalogued as COSV59916742; called by muse, mutect2, varscan2
- KALRN | c.5781G>A p.L1927= (on ENST00000360013 / NM_001024660.4; = p.L230= on NM_007064.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 27/161 reads (17%) | catalogued as COSV52254598; called by muse, mutect2, varscan2
- KAT6A | c.5469C>T p.L1823= | Silent (SNP) | VAF 15/142 reads (11%) | called by muse, mutect2
- LMTK3 | c.2694G>A p.E898= | Silent (SNP) | VAF 69/373 reads (18%) | called by muse, mutect2, varscan2
- LONP2 | c.2076G>A p.V692= | Silent (SNP) | VAF 23/65 reads (35%) | called by muse, mutect2, varscan2
- LRRC43 | c.1269C>T p.I423= | Silent (SNP) | VAF 8/84 reads (10%) | called by muse, mutect2
- LRRD1 | c.1974C>T p.I658= | Silent (SNP) | VAF 22/148 reads (15%) | catalogued as rs1403107419; called by muse, mutect2, varscan2
- LRRN2 | c.1714C>T p.L572= | Silent (SNP) | VAF 12/84 reads (14%) | called by muse, mutect2
- LY75 | c.2913C>T p.L971= | Silent (SNP) | VAF 64/359 reads (18%) | called by muse, mutect2, varscan2
- MAGEC2 | c.225G>A p.V75= | Silent (SNP) | VAF 20/133 reads (15%) | catalogued as rs1446087368, COSV55998346; called by muse, mutect2, varscan2
- MAGIX | c.411C>T p.L137= | Silent (SNP) | VAF 12/119 reads (10%) | called by muse, mutect2, varscan2
- MAPK13 | c.708G>A p.L236= | Silent (SNP) | VAF 22/160 reads (14%) | catalogued as COSV52984419; called by muse, varscan2
- MBP | c.168G>A p.G56= | Silent (SNP) | VAF 35/192 reads (18%) | called by muse, mutect2, varscan2
- MCAM | c.594G>A p.S198= | Silent (SNP) | VAF 22/140 reads (16%) | catalogued as rs757168667, COSV50652578; called by muse, mutect2, varscan2
- MEGF6 | c.1785G>A p.E595= | Silent (SNP) | VAF 33/186 reads (18%) | called by muse, mutect2
- MGMT | c.60G>A p.A20= | Silent (SNP) | VAF 26/165 reads (16%) | catalogued as rs951812151; called by muse, mutect2, varscan2
- MKRN2OS | c.612C>T p.F204= | Silent (SNP) | VAF 27/180 reads (15%) | called by muse, mutect2, varscan2
- MOB1A | c.177G>A p.V59= | Silent (SNP) | VAF 18/110 reads (16%) | catalogued as rs1316985918; called by muse, mutect2, varscan2
- MOGAT1 | c.6G>A p.K2= | Silent (SNP) | VAF 4/33 reads (12%) | called by muse, mutect2, varscan2
- MORC2 | c.384C>T p.L128= (on ENST00000397641 / NM_001303256.3; = p.L66= on NM_014941.3) | Silent (SNP) | VAF 13/99 reads (13%) | called by muse, mutect2, varscan2
- MYADML2 | c.729C>T p.L243= | Silent (SNP) | VAF 44/311 reads (14%) | called by muse, mutect2, varscan2
- MYCBP2 | c.13848C>T p.L4616= (on ENST00000357337; = p.L4654= on NM_015057.5) | Silent (SNP) | VAF 38/203 reads (19%) | called by muse, mutect2, varscan2
- MYH14 | c.2952G>A p.Q984= | Silent (SNP) | VAF 5/38 reads (13%) | catalogued as COSV51815311; called by muse, mutect2, varscan2
- NAT16 | c.603G>T p.A201= | Silent (SNP) | VAF 5/28 reads (18%) | catalogued as rs762298722; called by mutect2, varscan2
- NEPRO | c.12G>A p.A4= | Silent (SNP) | VAF 44/234 reads (19%) | called by muse, varscan2
- NEURL1 | c.285C>T p.F95= | Silent (SNP) | VAF 24/160 reads (15%) | catalogued as COSV63914757; called by muse, mutect2, varscan2
- NFKB2 | c.1663C>T p.L555= | Silent (SNP) | VAF 24/175 reads (14%) | catalogued as rs1223564773; called by muse, mutect2, varscan2
- NGB | c.337C>T p.L113= | Silent (SNP) | VAF 12/186 reads (6%) | called by muse, mutect2
- NRBP2 | c.1482C>T p.L494= | Silent (SNP) | VAF 24/171 reads (14%) | catalogued as rs926627974, COSV100589208; called by muse, mutect2, varscan2
- NTNG2 | c.852C>T p.I284= | Silent (SNP) | VAF 45/274 reads (16%) | catalogued as rs535593595, COSV62368527; called by muse, mutect2, varscan2
- NUDC | c.231G>A p.Q77= | Silent (SNP) | VAF 12/78 reads (15%) | called by muse, mutect2, varscan2
- NUDT17 | c.51G>A p.V17= | Silent (SNP) | VAF 11/74 reads (15%) | catalogued as rs782668957; called by muse, mutect2, varscan2
- NUP210L | c.45C>T p.L15= | Silent (SNP) | VAF 19/312 reads (6%) | catalogued as rs1279307302; called by muse, mutect2
- NXF3 | c.1081C>A p.R361= | Silent (SNP) | VAF 8/41 reads (20%) | catalogued as COSV67703268; called by muse, mutect2, varscan2
- OLFM1 | c.486G>A p.R162= (on ENST00000371793 / NM_001282611.2; = p.R144= on NM_014279.5) | Silent (SNP) | VAF 15/126 reads (12%) | called by muse, mutect2, varscan2
- OR5D13 | c.105C>T p.F35= | Silent (SNP) | VAF 28/211 reads (13%) | catalogued as rs775172669, COSV62332845; called by muse, mutect2, varscan2
- PAPPA | c.4158C>G p.S1386= | Silent (SNP) | VAF 10/90 reads (11%) | called by muse, mutect2, varscan2
- PBRM1 | c.4959G>A p.L1653= (on ENST00000296302 / NM_001366071.2; = p.L1546= on NM_018313.5) | Silent (SNP) | VAF 26/174 reads (15%) | catalogued as COSV56270835; called by muse, mutect2, varscan2
- PCDH15 | c.4182G>A p.V1394= | Silent (SNP) | VAF 43/137 reads (31%) | catalogued as COSV57269032; called by muse, mutect2, varscan2
- PCDHGA2 | c.2274C>A p.S758= | Silent (SNP) | VAF 13/74 reads (18%) | called by muse, mutect2, varscan2
- PCDHGB3 | c.588G>A p.L196= | Silent (SNP) | VAF 32/207 reads (15%) | catalogued as COSV53972771; called by muse, mutect2, varscan2
- PDZD2 | c.447G>A p.L149= | Silent (SNP) | VAF 14/116 reads (12%) | called by muse, mutect2, varscan2
- PEAK1 | c.4683G>A p.Q1561= | Silent (SNP) | VAF 31/202 reads (15%) | catalogued as rs748993516; called by muse, mutect2, varscan2
- PINX1 | c.873G>A p.L291= | Silent (SNP) | VAF 86/338 reads (25%) | catalogued as rs896095411; called by muse, varscan2
- PKHD1L1 | c.3366G>A p.L1122= | Silent (SNP) | VAF 18/129 reads (14%) | called by muse, mutect2, varscan2
- PKN1 | c.1332C>A p.L444= | Silent (SNP) | VAF 18/121 reads (15%) | called by muse, mutect2, varscan2
- PLXNA3 | c.1183C>T p.L395= | Silent (SNP) | VAF 15/79 reads (19%) | called by muse, mutect2, varscan2
- PLXNC1 | c.1635C>T p.L545= | Silent (SNP) | VAF 36/122 reads (30%) | called by muse, mutect2, varscan2
- POLR3A | c.4080C>T p.F1360= | Silent (SNP) | VAF 48/175 reads (27%) | called by muse, mutect2, varscan2
- PRMT2 | c.966G>A p.L322= | Silent (SNP) | VAF 14/90 reads (16%) | called by muse, mutect2, varscan2
- PRSS16 | c.603C>T p.L201= | Silent (SNP) | VAF 31/217 reads (14%) | called by muse, mutect2, varscan2
- PSKH1 | c.465C>T p.I155= | Silent (SNP) | VAF 30/170 reads (18%) | catalogued as rs760057627; called by muse, varscan2
- PTPN14 | c.2244C>T p.P748= | Silent (SNP) | VAF 84/185 reads (45%) | catalogued as COSV65284706; called by muse, mutect2, varscan2
- RAB27B | c.267C>T p.F89= | Silent (SNP) | VAF 27/191 reads (14%) | called by muse, mutect2, varscan2
- RDH5 | c.956G>A p.*319= | Silent (SNP) | VAF 74/483 reads (15%) | called by muse, varscan2
- REG1B | c.55C>T p.L19= | Silent (SNP) | VAF 34/247 reads (14%) | catalogued as COSV59307665; called by muse, mutect2, varscan2
- REV1 | c.426C>T p.L142= | Silent (SNP) | VAF 20/115 reads (17%) | called by muse, mutect2, varscan2
- RFX2 | c.1551C>T p.L517= | Silent (SNP) | VAF 9/54 reads (17%) | called by muse, mutect2, varscan2
- RSKR | c.366C>T p.L122= | Silent (SNP) | VAF 20/153 reads (13%) | catalogued as rs1393261991; called by muse, mutect2, varscan2
- SCNN1D | c.1875G>A p.E625= (on ENST00000338555; = p.E789= on NM_001130413.4) | Silent (SNP) | VAF 18/83 reads (22%) | catalogued as rs1389333072; called by muse, mutect2, varscan2
- SLC14A1 | c.912C>T p.L304= | Silent (SNP) | VAF 14/93 reads (15%) | called by muse, mutect2, varscan2
- SLC35F2 | c.972C>A p.V324= | Silent (SNP) | VAF 23/131 reads (18%) | called by muse, mutect2, varscan2
- SLC66A3 | c.111C>T p.L37= | Silent (SNP) | VAF 4/42 reads (10%) | catalogued as rs778665036; called by mutect2, varscan2
- SNED1 | c.1125C>T p.C375= | Silent (SNP) | VAF 6/138 reads (4%) | catalogued as rs1173949099, COSV60023639; called by muse, mutect2
- SORCS1 | c.3102C>G p.L1034= | Silent (SNP) | VAF 15/101 reads (15%) | catalogued as COSV53855212, COSV53902860; called by muse, mutect2, varscan2
- SPAG4 | c.264G>A p.Q88= | Silent (SNP) | VAF 8/63 reads (13%) | called by mutect2, varscan2
- SPPL2B | c.1593C>T p.L531= | Silent (SNP) | VAF 32/144 reads (22%) | called by muse, mutect2, varscan2
- ST8SIA3 | c.99G>C p.L33= | Silent (SNP) | VAF 44/327 reads (13%) | called by muse, mutect2, varscan2
- SYBU | c.147C>T p.F49= (on ENST00000276646 / NM_001099754.2; = p.F48= on NM_017786.6) | Silent (SNP) | VAF 9/82 reads (11%) | called by muse, mutect2, varscan2
- SYNE1 | c.23415G>A p.Q7805= (on ENST00000367255 / NM_182961.4; = p.Q7734= on NM_033071.3) | Silent (SNP) | VAF 15/173 reads (9%) | catalogued as COSV55021173; called by muse, mutect2
- SYT1 | c.1032C>T p.F344= | Silent (SNP) | VAF 14/114 reads (12%) | called by muse, mutect2, varscan2
- TM9SF1 | c.1512C>T p.V504= | Silent (SNP) | VAF 11/108 reads (10%) | called by muse, mutect2, varscan2
- TNK2 | c.2118C>A p.I706= | Silent (SNP) | VAF 19/141 reads (13%) | called by muse, mutect2, varscan2
- TOMM40L | c.90C>T p.F30= | Silent (SNP) | VAF 19/149 reads (13%) | called by muse, mutect2, varscan2
- TRAFD1 | c.492T>A p.I164= | Silent (SNP) | VAF 39/105 reads (37%) | called by muse, mutect2, varscan2
- TRIO | c.3279G>A p.V1093= | Silent (SNP) | VAF 31/171 reads (18%) | catalogued as COSV60094699; called by muse, mutect2, varscan2
- TSC2 | c.1572C>T p.F524= | Silent (SNP) | VAF 6/57 reads (11%) | called by muse, mutect2, varscan2
- TSR2 | c.324G>A p.L108= | Silent (SNP) | VAF 16/68 reads (24%) | called by muse, mutect2, varscan2
- UCKL1 | c.495C>T p.I165= | Silent (SNP) | VAF 47/288 reads (16%) | catalogued as rs551870482; called by muse, mutect2, varscan2
- UGGT2 | c.21G>A p.T7= | Silent (SNP) | VAF 26/58 reads (45%) | catalogued as rs752693358, COSV100942566, COSV65025390; called by muse, mutect2, varscan2
- ULBP3 | c.597G>C p.L199= | Silent (SNP) | VAF 10/154 reads (6%) | called by muse, mutect2
- VPS13A | c.888C>T p.F296= | Silent (SNP) | VAF 7/41 reads (17%) | called by muse, mutect2, varscan2
- VPS13C | c.7578C>G p.V2526= (on ENST00000644861 / NM_020821.3; = p.V2483= on NM_017684.5) | Silent (SNP) | VAF 23/158 reads (15%) | catalogued as rs201577606; called by muse, mutect2, varscan2
- ZAN | c.783C>T p.L261= | Silent (SNP) | VAF 19/167 reads (11%) | catalogued as COSV61807815; called by muse, mutect2, varscan2
- ZFP3 | c.564G>A p.L188= | Silent (SNP) | VAF 18/154 reads (12%) | catalogued as rs1252189074; called by muse, varscan2
- ZIC3 | c.948C>G p.V316= | Silent (SNP) | VAF 25/215 reads (12%) | called by muse, mutect2, varscan2
- ZNF106 | c.2730C>G p.L910= | Silent (SNP) | VAF 12/124 reads (10%) | called by muse, mutect2
- ZNF33B | c.1854C>T p.F618= | Silent (SNP) | VAF 25/147 reads (17%) | catalogued as COSV63942321, COSV63943561; called by muse, mutect2, varscan2
- ZNF585A | c.1173C>T p.F391= (on ENST00000292841 / NM_001288800.2; = p.F336= on NM_152655.3) | Silent (SNP) | VAF 45/262 reads (17%) | called by muse, varscan2
- ZNF691 | c.564G>A p.T188= (on ENST00000372502; = p.T157= on NM_015911.3) | Silent (SNP) | VAF 32/240 reads (13%) | catalogued as rs368463512; called by muse, varscan2
- ABCA1 | c.*237A>C | 3'UTR (SNP) | VAF 12/74 reads (16%) | called by mutect2, varscan2
- ABCG4 | c.239-707A>G | Intron (SNP) | VAF 9/28 reads (32%) | called by muse, mutect2, varscan2
- ABHD2 | c.*1832C>T | 3'UTR (SNP) | VAF 30/115 reads (26%) | called by muse, mutect2, varscan2
- ABI2 | c.*6406G>A | 3'UTR (SNP) | VAF 17/126 reads (13%) | called by muse, mutect2, varscan2
- ABTB1 | c.-42C>T | 5'UTR (SNP) | VAF 12/69 reads (17%) | catalogued as rs200194975, COSV99229578; called by muse, mutect2, varscan2
- AC009093.9 | n.445G>A | RNA (SNP) | VAF 38/290 reads (13%) | called by muse, mutect2, varscan2
- AC022905.1 | n.1274G>A | RNA (SNP) | VAF 18/138 reads (13%) | called by muse, mutect2, varscan2
- AC093791.1 | n.471C>T | RNA (SNP) | VAF 28/210 reads (13%) | catalogued as rs754706972; called by muse, mutect2, varscan2
- AC093890.1 | n.293C>T | RNA (SNP) | VAF 17/110 reads (15%) | called by muse, mutect2, varscan2
- AC105001.2 | c.-15C>T | 5'UTR (SNP) | VAF 33/204 reads (16%) | called by mutect2, varscan2
- AC106795.1 | n.1343C>G | RNA (SNP) | VAF 64/810 reads (8%) | called by muse, mutect2
- ACAA2 | chr18:49814426 G>C | 5'Flank (SNP) | VAF 28/185 reads (15%) | called by muse, mutect2, varscan2
- ACACA | c.*1141C>T | 3'UTR (SNP) | VAF 16/114 reads (14%) | called by muse, mutect2, varscan2
- ACAP3 | c.*851C>T | 3'UTR (SNP) | VAF 20/126 reads (16%) | catalogued as rs906935543; called by muse, mutect2, varscan2
- ACTB | c.363+39C>G | Intron (SNP) | VAF 12/81 reads (15%) | called by muse, mutect2, varscan2
- ACTR10 | c.635-52C>G | Intron (SNP) | VAF 12/115 reads (10%) | catalogued as rs1490883331; called by muse, mutect2, varscan2
- ACY1 | c.359+116G>A | Intron (SNP) | VAF 6/40 reads (15%) | called by muse, mutect2
- ADAMTS4 | c.*24C>T | 3'UTR (SNP) | VAF 13/69 reads (19%) | catalogued as COSV100917743; called by muse, mutect2, varscan2
- ADAP2 | chr17:30921751 C>T | 5'Flank (SNP) | VAF 38/135 reads (28%) | called by muse, mutect2, varscan2
- ADGRA3 | c.1809+631T>G | Intron (SNP) | VAF 18/71 reads (25%) | called by muse, mutect2, varscan2
- ADGRG6 | c.*1759G>C | 3'UTR (SNP) | VAF 23/56 reads (41%) | called by muse, mutect2, varscan2
- ADO | c.*1028C>T | 3'UTR (SNP) | VAF 9/48 reads (19%) | catalogued as rs1019688957; called by muse, mutect2, varscan2
- AFG3L1P | n.179-52C>G | Intron (SNP) | VAF 7/25 reads (28%) | called by muse, mutect2, varscan2
- AGPAT2 | c.*238C>T | 3'UTR (SNP) | VAF 32/176 reads (18%) | catalogued as rs1006928660; called by muse, varscan2
- AKAP17A | c.1153-586C>A | Intron (SNP) | VAF 27/174 reads (16%) | called by muse, mutect2, varscan2
- AKR1A1 | c.*85G>A | 3'UTR (SNP) | VAF 37/205 reads (18%) | called by muse, mutect2, varscan2
- AKT1S1 | chr19:49877937 C>T | 5'Flank (SNP) | VAF 29/184 reads (16%) | called by muse, varscan2
- ALG13 | c.*167G>A | 3'UTR (SNP) | VAF 14/75 reads (19%) | called by muse, mutect2, varscan2
- ALOX5 | c.*165C>G | 3'UTR (SNP) | VAF 31/183 reads (17%) | called by muse, mutect2, varscan2
- AMACR | c.*831G>A | 3'UTR (SNP) | VAF 61/443 reads (14%) | catalogued as rs1461044591; called by muse, mutect2, varscan2
- AMFR | c.*612C>G | 3'UTR (SNP) | VAF 52/256 reads (20%) | called by muse, mutect2, varscan2
- AMOT | c.2473+408G>A | Intron (SNP) | VAF 8/39 reads (21%) | called by muse, mutect2, varscan2
- AMPH | c.1272+1494G>A | Intron (SNP) | VAF 4/25 reads (16%) | called by muse, mutect2
- ANAPC4 | c.1623+61C>A | Intron (SNP) | VAF 8/41 reads (20%) | called by muse, mutect2, varscan2
- ANGPT2 | c.1330+415C>G | Intron (SNP) | VAF 8/34 reads (24%) | called by muse, mutect2, varscan2
- ANKRD12 | c.*1805G>A | 3'UTR (SNP) | VAF 42/99 reads (42%) | called by muse, mutect2, varscan2
- ANKRD42 | c.502+1528C>T | Intron (SNP) | VAF 29/214 reads (14%) | catalogued as rs752277921; called by muse, mutect2, varscan2
- ANKRD44 | c.*140G>C | 3'UTR (SNP) | VAF 9/86 reads (10%) | catalogued as rs961979244; called by muse, mutect2, varscan2
- AP000769.5 | chr11:65500559 G>A | 5'Flank (SNP) | VAF 18/141 reads (13%) | called by muse, mutect2, varscan2
- APOL1 | c.-20+746G>A | Intron (SNP) | VAF 24/156 reads (15%) | catalogued as rs757583570, COSV59870450; called by muse, mutect2, varscan2
- ARCN1 | c.*1285C>G | 3'UTR (SNP) | VAF 11/71 reads (15%) | catalogued as COSV99873795; called by muse, mutect2, varscan2
- ARF6 | c.*50C>T | 3'UTR (SNP) | VAF 146/600 reads (24%) | called by muse, varscan2
- ARHGEF1 | c.615-15C>T | Intron (SNP) | VAF 18/76 reads (24%) | called by muse, mutect2, varscan2
- ARHGEF4 | chr2:130915750 G>A | 5'Flank (SNP) | VAF 26/148 reads (18%) | catalogued as COSV100387927; called by muse, mutect2
- ARL4A | chr7:12689590 ins T | 3'Flank (INS) | VAF 39/81 reads (48%) | called by mutect2, varscan2
- ARRB1 | c.*1045G>A | 3'UTR (SNP) | VAF 17/124 reads (14%) | called by muse, mutect2, varscan2
- ARSB | c.1213+23529G>A | Intron (SNP) | VAF 11/98 reads (11%) | called by muse, mutect2, varscan2
- ART4 | c.*777C>T | 3'UTR (SNP) | VAF 32/75 reads (43%) | called by muse, mutect2, varscan2
- ASH1L | chr1:155562806 C>A | 5'Flank (SNP) | VAF 26/117 reads (22%) | called by mutect2, varscan2
- ASTN1 | c.*3105G>C | 3'UTR (SNP) | VAF 6/59 reads (10%) | called by muse, mutect2, varscan2
- ASTN1 | c.*448C>T | 3'UTR (SNP) | VAF 8/44 reads (18%) | called by muse, mutect2, varscan2
- ASXL1 | c.719-422C>T | Intron (SNP) | VAF 6/29 reads (21%) | called by muse, mutect2
- ATAD3B | c.282+1195C>T | Intron (SNP) | VAF 10/46 reads (22%) | catalogued as rs371404580, COSV58023885; called by muse, mutect2, varscan2
- ATF7 | c.*15G>C | 3'UTR (SNP) | VAF 7/46 reads (15%) | called by muse, mutect2, varscan2
- ATG4B | c.538+195G>C | Intron (SNP) | VAF 11/78 reads (14%) | called by muse, mutect2, varscan2
- ATM | c.*2581G>A | 3'UTR (SNP) | VAF 11/64 reads (17%) | called by muse, mutect2, varscan2
- ATP10B | c.*1913C>T | 3'UTR (SNP) | VAF 10/58 reads (17%) | called by muse, mutect2, varscan2
- ATP2B2 | c.*796C>A | 3'UTR (SNP) | VAF 15/75 reads (20%) | called by muse, mutect2, varscan2
- ATP2B3 | c.*972G>A | 3'UTR (SNP) | VAF 14/79 reads (18%) | called by muse, mutect2, varscan2
- ATP5F1C | c.-18A>T | 5'UTR (SNP) | VAF 53/195 reads (27%) | called by muse, mutect2, varscan2
- ATXN1 | c.*4525C>T | 3'UTR (SNP) | VAF 25/168 reads (15%) | catalogued as rs1021197867; called by muse, mutect2, varscan2
- AVL9 | c.*2964C>T | 3'UTR (SNP) | VAF 53/121 reads (44%) | called by muse, mutect2, varscan2
- BAG3 | c.180+5692G>C | Intron (SNP) | VAF 27/155 reads (17%) | called by muse, mutect2, varscan2
- BLNK | c.-97G>A | 5'UTR (SNP) | VAF 23/139 reads (17%) | called by muse, varscan2
- BNIPL | c.*1014G>C | 3'UTR (SNP) | VAF 20/105 reads (19%) | called by muse, mutect2, varscan2
- BPGM | c.*478G>C | 3'UTR (SNP) | VAF 18/110 reads (16%) | called by muse, mutect2, varscan2
- BRAF | c.1862-130G>A | Intron (SNP) | VAF 5/22 reads (23%) | called by muse, mutect2, varscan2
- C10orf71 | c.*568G>A | 3'UTR (SNP) | VAF 20/124 reads (16%) | called by muse, mutect2, varscan2
- C11orf52 | c.*629C>T | 3'UTR (SNP) | VAF 9/80 reads (11%) | catalogued as rs1185795783; called by muse, mutect2
- C18orf54 | c.*176C>T | 3'UTR (SNP) | VAF 14/68 reads (21%) | called by muse, mutect2, varscan2
- C20orf197 | n.536T>C | RNA (SNP) | VAF 69/255 reads (27%) | catalogued as rs1361490706; called by muse, mutect2, varscan2
- CACNA1D | c.4793-45C>T | Intron (SNP) | VAF 6/37 reads (16%) | called by muse, mutect2
- CACNA1E | c.*3524G>C | 3'UTR (SNP) | VAF 34/175 reads (19%) | called by muse, mutect2, varscan2
- CACNA2D4 | c.-85G>A | 5'UTR (SNP) | VAF 7/44 reads (16%) | called by muse, mutect2, varscan2
- CACNB4 | c.148-90523C>T | Intron (SNP) | VAF 12/125 reads (10%) | called by muse, mutect2
- CAMKK2 | c.*1835G>A | 3'UTR (SNP) | VAF 29/74 reads (39%) | called by muse, mutect2, varscan2
- CAPN12 | c.1363-54G>A | Intron (SNP) | VAF 22/157 reads (14%) | called by muse, mutect2, varscan2
- CAV1 | c.*451C>T | 3'UTR (SNP) | VAF 8/115 reads (7%) | called by muse, mutect2
- CBLN3 | c.-98G>A | 5'UTR (SNP) | VAF 86/482 reads (18%) | called by muse, varscan2
- CCDC32 | c.-191G>A | 5'UTR (SNP) | VAF 33/183 reads (18%) | called by muse, mutect2, varscan2
- CCDC6 | c.-108C>G | 5'UTR (SNP) | VAF 10/71 reads (14%) | called by muse, mutect2, varscan2
- CCDC93 | c.*2499C>T | 3'UTR (SNP) | VAF 27/138 reads (20%) | called by muse, mutect2, varscan2
- CCNJL | c.-39G>C | 5'UTR (SNP) | VAF 12/91 reads (13%) | called by muse, mutect2, varscan2
- CD300E | c.*2528C>G | 3'UTR (SNP) | VAF 26/189 reads (14%) | called by muse, mutect2, varscan2
- CD300LD | c.*134C>T | 3'UTR (SNP) | VAF 6/70 reads (9%) | catalogued as rs1174099156; called by muse, mutect2
- CDC37L1 | c.-178G>A | 5'UTR (SNP) | VAF 21/148 reads (14%) | called by muse, mutect2, varscan2
- CDCP1 | c.*610C>A | 3'UTR (SNP) | VAF 14/118 reads (12%) | called by muse, mutect2, varscan2
- CENPP | c.*2380A>G | 3'UTR (SNP) | VAF 10/58 reads (17%) | called by muse, mutect2, varscan2
- CEP170P1 | n.4492G>A | RNA (SNP) | VAF 36/218 reads (17%) | catalogued as rs1416035974; called by muse, varscan2
- CEP78 | c.*8459G>A | 3'UTR (SNP) | VAF 12/84 reads (14%) | called by mutect2, varscan2
- CETP | c.598-46C>T | Intron (SNP) | VAF 15/56 reads (27%) | called by muse, mutect2, varscan2
- CFAP97 | c.1321-5155C>T | Intron (SNP) | VAF 40/82 reads (49%) | called by muse, mutect2, varscan2
- CFL2 | c.*1389G>C | 3'UTR (SNP) | VAF 11/82 reads (13%) | called by mutect2, varscan2
- CHRNE | c.*14C>T | 3'UTR (SNP) | VAF 13/118 reads (11%) | called by muse, mutect2
- CHST1 | c.*261C>G | 3'UTR (SNP) | VAF 14/73 reads (19%) | called by muse, mutect2, varscan2
- CHST13 | c.*286G>A | 3'UTR (SNP) | VAF 40/150 reads (27%) | catalogued as rs777053857; called by muse, mutect2, varscan2
- CHST15 | c.*855C>T | 3'UTR (SNP) | VAF 8/45 reads (18%) | called by muse, mutect2, varscan2
- CISD2 | c.-58G>A | 5'UTR (SNP) | VAF 6/28 reads (21%) | called by muse, mutect2, varscan2
- CLCN4 | c.*3428C>G | 3'UTR (SNP) | VAF 15/122 reads (12%) | called by muse, mutect2, varscan2
- CLDN9 | c.*233A>G | 3'UTR (SNP) | VAF 34/122 reads (28%) | called by muse, mutect2, varscan2
- CLINT1 | c.*303G>A | 3'UTR (SNP) | VAF 20/121 reads (17%) | called by muse, mutect2, varscan2
- CNNM2 | c.*1039C>G | 3'UTR (SNP) | VAF 33/143 reads (23%) | catalogued as rs1446936818; called by muse, mutect2, varscan2
- COL1A1 | c.3262-11C>G | Intron (SNP) | VAF 33/245 reads (13%) | called by muse, mutect2, varscan2
- COL4A6 | c.66+54128C>T | Intron (SNP) | VAF 16/113 reads (14%) | catalogued as rs1022279529; called by muse, mutect2, varscan2
- COLCA2 | chr11:111294429 C>T | 5'Flank (SNP) | VAF 18/97 reads (19%) | called by muse, mutect2, varscan2
- CPA1 | c.*34C>G | 3'UTR (SNP) | VAF 19/207 reads (9%) | called by muse, mutect2
- CPS1 | c.4102-54A>G | Intron (SNP) | VAF 8/25 reads (32%) | called by muse, mutect2
- CPSF3 | c.1856+71G>T | Intron (SNP) | VAF 9/49 reads (18%) | called by muse, mutect2, varscan2
- CSK | c.15+117C>T | Intron (SNP) | VAF 16/129 reads (12%) | called by muse, mutect2, varscan2
- CTNNAL1 | c.-7G>A | 5'UTR (SNP) | VAF 9/57 reads (16%) | called by muse, mutect2, varscan2
- CTSH | c.807-16G>A | Intron (SNP) | VAF 21/106 reads (20%) | called by muse, mutect2, varscan2
- CYTH1 | c.23-18020G>A | Intron (SNP) | VAF 27/165 reads (16%) | called by muse, mutect2, varscan2
- CYTL1 | c.*182G>C | 3'UTR (SNP) | VAF 15/80 reads (19%) | called by muse, mutect2, varscan2
- DIAPH2 | c.*2049G>A | 3'UTR (SNP) | VAF 13/122 reads (11%) | catalogued as rs1224354172; called by muse, mutect2, varscan2
- DLGAP2 | c.*6824G>A | 3'UTR (SNP) | VAF 6/63 reads (10%) | catalogued as rs1191829123; called by muse, mutect2
- DMXL1 | c.*1741C>T | 3'UTR (SNP) | VAF 15/70 reads (21%) | called by muse, mutect2, varscan2
- DPH6 | c.312+17735G>A | Intron (SNP) | VAF 13/66 reads (20%) | called by muse, mutect2, varscan2
- DPH6 | c.312+16128G>C | Intron (SNP) | VAF 25/165 reads (15%) | called by muse, mutect2, varscan2
- DPY19L2 | c.-84C>T | 5'UTR (SNP) | VAF 5/28 reads (18%) | called by muse, mutect2
- DRD2 | c.810+131G>A | Intron (SNP) | VAF 3/22 reads (14%) | called by muse, mutect2
- DUOXA1 | chr15:45119032 C>T | 3'Flank (SNP) | VAF 3/28 reads (11%) | called by muse, mutect2
- E2F6 | c.109-1075G>A | Intron (SNP) | VAF 18/146 reads (12%) | called by muse, mutect2, varscan2
- EDARADD | c.*1189A>G | 3'UTR (SNP) | VAF 19/203 reads (9%) | called by muse, mutect2
- EEF1AKMT3 | c.*975G>A | 3'UTR (SNP) | VAF 18/167 reads (11%) | catalogued as rs1012713331; called by muse, mutect2, varscan2
- EEF1AKNMT | c.-243G>A | 5'UTR (SNP) | VAF 19/141 reads (13%) | catalogued as rs1408098422; called by muse, mutect2, varscan2
- EGR3 | c.*140C>G | 3'UTR (SNP) | VAF 8/48 reads (17%) | catalogued as rs976571798; called by muse, mutect2
- ELF5 | c.385+777C>T | Intron (SNP) | VAF 13/95 reads (14%) | catalogued as rs955995483; called by muse, mutect2, varscan2
- ELK3 | c.*579G>C | 3'UTR (SNP) | VAF 16/96 reads (17%) | called by muse, mutect2, varscan2
- EML2 | c.21-130C>T | Intron (SNP) | VAF 20/50 reads (40%) | called by muse, mutect2, varscan2
- EPAS1 | c.*52C>T | 3'UTR (SNP) | VAF 6/68 reads (9%) | called by muse, mutect2
- EPM2A | c.*1132G>A | 3'UTR (SNP) | VAF 6/80 reads (8%) | catalogued as rs1013357999; called by muse, mutect2
- ERMARD | c.990+412C>G | Intron (SNP) | VAF 18/141 reads (13%) | called by muse, mutect2, varscan2
- ESPNL | c.*1492G>C | 3'UTR (SNP) | VAF 11/109 reads (10%) | called by muse, mutect2, varscan2
- ESR1 | c.*2973C>T | 3'UTR (SNP) | VAF 6/47 reads (13%) | called by muse, mutect2, varscan2
- EVA1A | c.*188C>G | 3'UTR (SNP) | VAF 4/66 reads (6%) | called by muse, mutect2
- F3 | c.*1096G>C | 3'UTR (SNP) | VAF 5/24 reads (21%) | called by muse, mutect2, varscan2
- FAM120C | c.*2917G>A | 3'UTR (SNP) | VAF 8/96 reads (8%) | called by muse, mutect2
- FAM124A | c.834+94C>T | Intron (SNP) | VAF 5/46 reads (11%) | called by muse, mutect2, varscan2
- FAM169B | n.819C>G | RNA (SNP) | VAF 7/52 reads (13%) | called by muse, mutect2, varscan2
- FAM78B | c.-136C>T | 5'UTR (SNP) | VAF 4/16 reads (25%) | called by muse, mutect2
- FAT3 | c.*4960G>A | 3'UTR (SNP) | VAF 12/51 reads (24%) | called by muse, mutect2, varscan2
- FEM1C | c.*2505C>G | 3'UTR (SNP) | VAF 15/100 reads (15%) | catalogued as rs1194496534; called by mutect2, varscan2
- FEM1C | c.*263C>T | 3'UTR (SNP) | VAF 39/129 reads (30%) | catalogued as rs1180993411; called by muse, mutect2, varscan2
- FGD4 | c.2043+104C>T | Intron (SNP) | VAF 10/72 reads (14%) | catalogued as rs117875400; called by muse, mutect2, varscan2
- FKBP14 | c.*3968G>A | 3'UTR (SNP) | VAF 11/60 reads (18%) | called by muse, mutect2, varscan2
- FSD2 | c.*987C>T | 3'UTR (SNP) | VAF 19/114 reads (17%) | called by muse, mutect2, varscan2
- FZD3 | c.*7216C>T | 3'UTR (SNP) | VAF 4/14 reads (29%) | catalogued as rs995544656; called by muse, mutect2
- GAB3 | c.*2804C>T | 3'UTR (SNP) | VAF 25/99 reads (25%) | called by muse, mutect2, varscan2
- GABPA | c.-175C>T | 5'UTR (SNP) | VAF 21/99 reads (21%) | called by muse, mutect2, varscan2
- GAREM1 | c.*4144G>A | 3'UTR (SNP) | VAF 13/100 reads (13%) | called by muse, mutect2, varscan2
- GCNT1 | c.*1765C>T | 3'UTR (SNP) | VAF 13/80 reads (16%) | called by muse, mutect2, varscan2
- GIGYF2 | c.*654G>A | 3'UTR (SNP) | VAF 5/55 reads (9%) | catalogued as rs1205102505; called by muse, mutect2
- GIMAP1 | c.*2474C>G | 3'UTR (SNP) | VAF 22/140 reads (16%) | called by muse, mutect2, varscan2
- GMPS | c.-198C>T | 5'UTR (SNP) | VAF 3/33 reads (9%) | called by muse, mutect2
- GNL1 | c.*3138G>A | 3'UTR (SNP) | VAF 12/177 reads (7%) | called by muse, mutect2
- GNL1 | c.*1265C>T | 3'UTR (SNP) | VAF 23/89 reads (26%) | called by muse, mutect2, varscan2
- GORAB | c.662+225C>G | Intron (SNP) | VAF 11/55 reads (20%) | called by muse, mutect2, varscan2
- GP2 | c.*712G>C | 3'UTR (SNP) | VAF 18/82 reads (22%) | called by muse, mutect2, varscan2
- GPM6A | c.*1605C>T | 3'UTR (SNP) | VAF 20/156 reads (13%) | catalogued as COSV99705583; called by muse, varscan2
- GPR135 | c.*1715C>T | 3'UTR (SNP) | VAF 14/63 reads (22%) | called by muse, mutect2, varscan2
- GPR55 | chr2:230909460 C>T | 3'Flank (SNP) | VAF 15/159 reads (9%) | catalogued as rs1177804739; called by muse, mutect2, varscan2
- GPR85 | c.*174G>A | 3'UTR (SNP) | VAF 3/41 reads (7%) | called by muse, mutect2
- GPRIN3 | c.*1465C>T | 3'UTR (SNP) | VAF 21/121 reads (17%) | called by muse, mutect2, varscan2
- GRIN2A | c.*5092C>G | 3'UTR (SNP) | VAF 14/77 reads (18%) | called by muse, mutect2, varscan2
- GSG1L2 | c.512-81C>G | Intron (SNP) | VAF 3/16 reads (19%) | called by muse, mutect2
- GUCD1 | c.*99G>C | 3'UTR (SNP) | VAF 9/53 reads (17%) | called by muse, mutect2, varscan2
- HFE | c.*163G>C | 3'UTR (SNP) | VAF 96/562 reads (17%) | called by muse, mutect2, varscan2
- HGH1 | c.*223G>A | 3'UTR (SNP) | VAF 16/86 reads (19%) | called by muse, mutect2, varscan2
- HMGN2 | c.91-110G>A | Intron (SNP) | VAF 10/120 reads (8%) | called by muse, mutect2
- HOPX | c.*401G>A | 3'UTR (SNP) | VAF 32/71 reads (45%) | called by muse, mutect2, varscan2
- HTR5A | chr7:155069039 G>A | 5'Flank (SNP) | VAF 21/133 reads (16%) | called by muse, mutect2, varscan2
- ID2 | c.-84G>A | 5'UTR (SNP) | VAF 5/57 reads (9%) | catalogued as rs1207369472; called by muse, mutect2
- IDH2 | c.*471G>A | 3'UTR (SNP) | VAF 15/115 reads (13%) | called by muse, mutect2, varscan2
- IER3 | c.*542C>T | 3'UTR (SNP) | VAF 25/170 reads (15%) | called by muse, mutect2, varscan2
- IGIP | c.-107C>G | 5'UTR (SNP) | VAF 11/50 reads (22%) | called by muse, mutect2, varscan2
- IGLV1-44 | c.-16C>G | 5'UTR (SNP) | VAF 19/60 reads (32%) | catalogued as rs1413283186; called by muse, mutect2, varscan2
- IGSF10 | c.*1395G>C | 3'UTR (SNP) | VAF 18/70 reads (26%) | called by muse, mutect2, varscan2
- IGSF11 | c.-29G>A | 5'UTR (SNP) | VAF 9/47 reads (19%) | called by mutect2, varscan2
- IGSF8 | chr1:160098630 C>T | 5'Flank (SNP) | VAF 22/57 reads (39%) | called by muse, mutect2, varscan2
- ILDR1 | c.*59C>T | 3'UTR (SNP) | VAF 57/357 reads (16%) | called by muse, mutect2, varscan2
- INPP5B | c.772+950G>C | Intron (SNP) | VAF 27/196 reads (14%) | called by muse, mutect2, varscan2
- INPP5D | chr2:233060099 C>T | 5'Flank (SNP) | VAF 10/142 reads (7%) | called by muse, mutect2
- INSM2 | c.-5C>T | 5'UTR (SNP) | VAF 29/89 reads (33%) | called by muse, mutect2, varscan2
- IPCEF1 | c.*2907C>T | 3'UTR (SNP) | VAF 10/96 reads (10%) | catalogued as rs953553000; called by muse, mutect2, varscan2
- IPO5 | c.*462C>G | 3'UTR (SNP) | VAF 4/16 reads (25%) | called by muse, mutect2
- IQCH | c.*276G>C | 3'UTR (SNP) | VAF 5/87 reads (6%) | called by muse, mutect2
- IRF1 | c.88-68C>G | Intron (SNP) | VAF 10/88 reads (11%) | called by muse, mutect2, varscan2
- IRF4 | c.-108C>T | 5'UTR (SNP) | VAF 15/82 reads (18%) | called by muse, mutect2, varscan2
- ITGA9 | c.*2892G>T | 3'UTR (SNP) | VAF 8/45 reads (18%) | called by muse, mutect2, varscan2
- KBTBD6 | c.*2337G>A | 3'UTR (SNP) | VAF 8/143 reads (6%) | called by muse, mutect2
- KCNJ11 | c.*360G>A | 3'UTR (SNP) | VAF 25/214 reads (12%) | catalogued as rs561755715; called by muse, mutect2, varscan2
- KCNK5 | c.*1097G>C | 3'UTR (SNP) | VAF 20/121 reads (17%) | called by muse, mutect2, varscan2
- KCNN2 | c.*249C>T | 3'UTR (SNP) | VAF 13/83 reads (16%) | called by muse, mutect2, varscan2
- KIAA0319L | c.*238C>T | 3'UTR (SNP) | VAF 11/69 reads (16%) | called by muse, mutect2, varscan2
- KLHDC4 | c.*167C>G | 3'UTR (SNP) | VAF 16/122 reads (13%) | called by muse, mutect2, varscan2
- KLHL31 | c.*66C>G | 3'UTR (SNP) | VAF 42/283 reads (15%) | called by muse, mutect2, varscan2
- KLRG2 | c.*448C>A | 3'UTR (SNP) | VAF 31/201 reads (15%) | called by muse, mutect2, varscan2
- KLRG2 | c.*447T>A | 3'UTR (SNP) | VAF 31/200 reads (16%) | called by muse, mutect2, varscan2
- KRT83 | c.*288C>T | 3'UTR (SNP) | VAF 14/66 reads (21%) | called by muse, mutect2, varscan2
- L3MBTL4 | c.*530G>A | 3'UTR (SNP) | VAF 8/59 reads (14%) | called by muse, mutect2, varscan2
- LAMP1 | c.*105C>A | 3'UTR (SNP) | VAF 13/99 reads (13%) | called by muse, mutect2, varscan2
- LBX2 | chr2:74502645 C>T | 5'Flank (SNP) | VAF 23/181 reads (13%) | called by muse, mutect2, varscan2
- LEKR1 | c.*481G>A | 3'UTR (SNP) | VAF 27/174 reads (16%) | called by muse, mutect2, varscan2
- LIMS1 | c.*95G>A | 3'UTR (SNP) | VAF 26/152 reads (17%) | catalogued as COSV100185591; called by muse, mutect2, varscan2
- LINC01098 | n.971C>T | RNA (SNP) | VAF 22/170 reads (13%) | called by muse, mutect2, varscan2
- LINC01556 | n.345C>T | RNA (SNP) | VAF 9/52 reads (17%) | called by muse, mutect2, varscan2
- LINC02872 | n.1165G>A | RNA (SNP) | VAF 17/91 reads (19%) | called by muse, mutect2, varscan2
- LIPC | c.1388+2306C>G | Intron (SNP) | VAF 8/38 reads (21%) | called by mutect2, varscan2
- LSM11 | c.*751C>T | 3'UTR (SNP) | VAF 24/172 reads (14%) | called by muse, mutect2, varscan2
- LYPD1 | c.-142C>G | 5'UTR (SNP) | VAF 7/49 reads (14%) | called by mutect2, varscan2
- LYRM2 | c.*773G>C | 3'UTR (SNP) | VAF 15/126 reads (12%) | called by muse, mutect2, varscan2
- MACF1 | c.543+10910G>C | Intron (SNP) | VAF 19/169 reads (11%) | called by muse, mutect2, varscan2
- MAD1L1 | c.1999-33113G>C | Intron (SNP) | VAF 15/153 reads (10%) | catalogued as rs1280131245; called by muse, mutect2, varscan2
- MAP4K4 | chr2:101892863 G>A | 3'Flank (SNP) | VAF 23/157 reads (15%) | catalogued as COSV56337413; called by muse, mutect2, varscan2
- MAP4K5 | c.1016-32G>C | Intron (SNP) | VAF 10/90 reads (11%) | called by muse, mutect2, varscan2
- MARCHF7 | c.*342G>A | 3'UTR (SNP) | VAF 13/69 reads (19%) | called by muse, mutect2, varscan2
- MARK2 | c.55-6376G>A | Intron (SNP) | VAF 13/111 reads (12%) | called by muse, mutect2, varscan2
- MAT2B | c.*274C>T | 3'UTR (SNP) | VAF 16/85 reads (19%) | called by muse, mutect2, varscan2
- MAVS | c.*2189C>T | 3'UTR (SNP) | VAF 5/45 reads (11%) | called by muse, mutect2
- MCRIP2 | c.412+103C>G | Intron (SNP) | VAF 16/100 reads (16%) | called by muse, mutect2, varscan2
- MECR | c.*1045G>A | 3'UTR (SNP) | VAF 12/122 reads (10%) | called by muse, mutect2
- MEIS2 | c.*1470G>A | 3'UTR (SNP) | VAF 18/113 reads (16%) | called by muse, mutect2, varscan2
- METAP1D | c.*1551C>G | 3'UTR (SNP) | VAF 16/132 reads (12%) | called by muse, mutect2, varscan2
- METTL15P1 | n.930G>C | RNA (SNP) | VAF 23/167 reads (14%) | called by muse, mutect2, varscan2
- MFAP5 | c.*2046C>G | 3'UTR (SNP) | VAF 17/157 reads (11%) | called by muse, mutect2, varscan2
- MGLL | c.233-13157G>A | Intron (SNP) | VAF 14/93 reads (15%) | called by muse, mutect2, varscan2
- MIDEAS | c.*3891G>A | 3'UTR (SNP) | VAF 12/59 reads (20%) | called by muse, mutect2, varscan2
- MRPL45P2 | n.696C>T | RNA (SNP) | VAF 30/162 reads (19%) | called by muse, mutect2, varscan2
- MRPL55 | c.-110G>C | 5'UTR (SNP) | VAF 24/137 reads (18%) | called by muse, mutect2, varscan2
- MSC | c.*285C>T | 3'UTR (SNP) | VAF 20/177 reads (11%) | called by muse, mutect2, varscan2
- MTCH2 | c.*291C>T | 3'UTR (SNP) | VAF 12/54 reads (22%) | called by muse, mutect2, varscan2
- MTDH | c.-112G>A | 5'UTR (SNP) | VAF 14/93 reads (15%) | catalogued as rs970509581; called by muse, mutect2, varscan2
- MTG1 | c.*1282C>G | 3'UTR (SNP) | VAF 42/96 reads (44%) | called by muse, mutect2, varscan2
- MTHFD2 | c.*1395C>T | 3'UTR (SNP) | VAF 7/52 reads (13%) | called by muse, mutect2, varscan2
- MTR | c.*4202C>A | 3'UTR (SNP) | VAF 12/88 reads (14%) | called by muse, mutect2, varscan2
- MYO10 | c.*1096G>C | 3'UTR (SNP) | VAF 21/134 reads (16%) | catalogued as rs1379942921; called by muse, mutect2, varscan2
- MYOM3 | c.3535-25C>G | Intron (SNP) | VAF 13/71 reads (18%) | called by muse, mutect2, varscan2
- MYRF | c.3301-31C>G | Intron (SNP) | VAF 20/155 reads (13%) | called by muse, mutect2, varscan2
- NAT8L | c.*2536C>T | 3'UTR (SNP) | VAF 50/130 reads (38%) | called by muse, mutect2, varscan2
- NCKAP5L | c.*77G>T | 3'UTR (SNP) | VAF 8/54 reads (15%) | called by muse, mutect2, varscan2
- NDRG2 | c.-6-253G>A | Intron (SNP) | VAF 21/147 reads (14%) | catalogued as rs1271951477; called by muse, mutect2, varscan2
- NDRG4 | c.373-136C>G | Intron (SNP) | VAF 25/197 reads (13%) | called by muse, mutect2, varscan2
- NEDD8 | c.-72G>A | 5'UTR (SNP) | VAF 20/149 reads (13%) | called by muse, mutect2, varscan2
- NEMF | c.*858C>T | 3'UTR (SNP) | VAF 12/100 reads (12%) | called by mutect2, varscan2
- NKAP | c.*4384G>A | 3'UTR (SNP) | VAF 5/35 reads (14%) | called by muse, mutect2, varscan2
- NKIRAS2 | c.*1631G>A | 3'UTR (SNP) | VAF 20/135 reads (15%) | called by muse, mutect2, varscan2
- NLK | c.*1552G>A | 3'UTR (SNP) | VAF 10/112 reads (9%) | called by muse, mutect2
- NLN | c.*2251C>G | 3'UTR (SNP) | VAF 6/66 reads (9%) | called by muse, mutect2
- NME6 | c.*125G>A | 3'UTR (SNP) | VAF 12/82 reads (15%) | called by muse, mutect2, varscan2
- NOL4 | c.*1672C>G | 3'UTR (SNP) | VAF 11/71 reads (15%) | called by muse, mutect2, varscan2
- NOS1AP | c.940-962C>T | Intron (SNP) | VAF 21/155 reads (14%) | called by muse, mutect2, varscan2
- NPEPL1 | c.*52G>A | 3'UTR (SNP) | VAF 35/216 reads (16%) | called by muse, mutect2, varscan2
- NPY2R | c.*466C>T | 3'UTR (SNP) | VAF 10/44 reads (23%) | called by mutect2, varscan2
- NPY6R | n.979G>A | RNA (SNP) | VAF 76/496 reads (15%) | catalogued as rs1323648112; called by muse, mutect2, varscan2
- NRK | c.490-103C>G | Intron (SNP) | VAF 12/78 reads (15%) | called by muse, mutect2, varscan2
213 further variants in this file (0 protein-altering or splice-affecting, 0 silent, 213 other) are not listed here.
